Somatic mutation profile of tumor specimen C3L-07546-01 (aliquot CPT0430030006) from CPTAC case C3L-07546, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 68.0 years (24,827 days).
Specimen C3L-07546-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e3882935-2f10-474d-ac59-7c048878936a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-07546-31 (Blood Derived Normal), aliquot CPT0430180004; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f0cbaea4-1d6a-41ca-a527-e2fd316f7364

The open-access MAF lists 1,906 somatic variants for this specimen: 1,419 protein-altering or splice-affecting, 411 silent, 76 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 977, Silent 411, Frame Shift Del 274, Frame Shift Ins 67, Nonsense Mutation 59, Intron 38, 3'UTR 15, Splice Region 15, In Frame Del 12, Splice Site 11, 5'Flank 8, 5'UTR 7.

Variants (750 of 1,906; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTSL4 | c.2594G>A p.R865H | Missense Mutation (SNP) | VAF 87/473 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781691587, CM146307; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ASNS | c.1649G>A p.R550H | Missense Mutation (SNP) | VAF 54/295 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs552452349, COSV51554162; ClinVar: likely pathogenic; called by muse, varscan2
- BNC2 | c.1723A>C p.S575R | Missense Mutation (SNP) | VAF 52/318 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.023); catalogued as rs1374823674, COSV66140362; called by muse, varscan2
- BRCA1 | c.1961del p.K654Sfs*47 | Frame Shift Del (DEL) | VAF 70/364 reads (19%) | catalogued as rs80357522, CD076746, CD951610; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by mutect2, varscan2
- DSG2 | c.2533del p.I845* | Frame Shift Del (DEL) | VAF 53/354 reads (15%) | catalogued as rs1375081885; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- ERBB2 | c.2033G>A p.R678Q | Missense Mutation (SNP) | VAF 67/390 reads (17%) | hotspot (GDC flag); SIFT tolerated (0.19); PolyPhen benign (0.103); catalogued as rs1057519862, COSV54062926; ClinVar: likely pathogenic / not provided; called by muse, mutect2, varscan2
- FGD1 | c.527del p.P176Hfs*39 | Frame Shift Del (DEL) | VAF 30/78 reads (38%) | catalogued as rs756586058; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- FZD4 | c.666G>A p.W222* | Nonsense Mutation (SNP) | VAF 82/442 reads (19%) | catalogued as rs1555085637; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GNAS | c.478C>T p.R160C | Missense Mutation (SNP) | VAF 43/304 reads (14%) | hotspot (GDC flag); SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as CM002273, COSV55670863; called by muse, mutect2, varscan2
- HTRA2 | c.1211G>A p.R404Q | Missense Mutation (SNP) | VAF 35/232 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.362); catalogued as rs767006508, COSV51206348; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 50/248 reads (20%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- NOTCH3 | c.544C>T p.R182C | Missense Mutation (SNP) | VAF 119/529 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs28933697, CM961044, COSV54637078; ClinVar: pathogenic; called by muse, mutect2, varscan2
- P3H1 | c.747del p.Y250Mfs*87 | Frame Shift Del (DEL) | VAF 75/390 reads (19%) | catalogued as rs72659348, CD071365; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PIK3CA | c.3061T>C p.Y1021H | Missense Mutation (SNP) | VAF 62/405 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV55901519, COSV55910253; called by muse, mutect2, varscan2
- SACS | c.8793del p.K2931Nfs*22 | Frame Shift Del (DEL) | VAF 64/344 reads (19%) | catalogued as rs767871841, CD056854; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- ZNF469 | c.10248del p.R3417Gfs*56 (on ENST00000437464; = p.R3445Gfs*56 on NM_001367624.2) | Frame Shift Del (DEL) | VAF 91/512 reads (18%) | catalogued as rs764470052, COSV99081573; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- AARS2 | c.785G>A p.R262Q | Missense Mutation (SNP) | VAF 52/368 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs139974034; ClinVar: uncertain significance; called by muse, varscan2
- ABCB4 | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 14/444 reads (3%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.01); catalogued as COSV99709878; called by muse, mutect2
- ABCC1 | c.2651C>T p.T884M | Missense Mutation (SNP) | VAF 56/328 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.046); catalogued as rs751066573, COSV100578733; called by muse, varscan2
- ABCC8 | c.766G>A p.A256T | Missense Mutation (SNP) | VAF 20/365 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.266); catalogued as rs1329684895, COSV56851349; called by muse, mutect2
- AC011005.1 | c.1211C>T p.T404M | Missense Mutation (SNP) | VAF 37/225 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); catalogued as rs1394925480; called by muse, mutect2, varscan2
- AC068580.4 | c.1085G>A p.G362D | Missense Mutation (SNP) | VAF 77/440 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); catalogued as COSV52590963; called by muse, mutect2, varscan2
- AC109583.1 | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 75/447 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); catalogued as rs768769548, COSV59350985; called by muse, mutect2, varscan2
- AC138647.1 | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 109/573 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.307); catalogued as rs759179877, COSV101447631; called by muse, mutect2, varscan2
- ACAP3 | c.2054C>T p.A685V | Missense Mutation (SNP) | VAF 106/576 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs771214380; called by muse, mutect2, varscan2
- ACAP3 | c.1636C>T p.R546C | Missense Mutation (SNP) | VAF 105/555 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as rs200579243; called by muse, mutect2, varscan2
- ACTN1 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 64/344 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.234); catalogued as rs371830470; called by muse, mutect2, varscan2
- ACTN2 | c.2540C>T p.A847V | Missense Mutation (SNP) | VAF 54/322 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs370569935; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACTN4 | c.2619del p.D874Tfs*44 | Frame Shift Del (DEL) | VAF 85/449 reads (19%) | catalogued as rs869292397; called by mutect2, pindel, varscan2
- ACTR3B | c.482G>A p.R161H | Missense Mutation (SNP) | VAF 36/269 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.953); catalogued as rs1310001405; called by muse, varscan2
- ACY3 | c.746A>G p.D249G | Missense Mutation (SNP) | VAF 49/232 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99663219; called by muse, mutect2, varscan2
- ADAM12 | c.1834C>T p.R612W | Missense Mutation (SNP) | VAF 75/469 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs969958267, COSV64103769; called by muse, mutect2
- ADAM28 | c.251C>T p.T84M | Missense Mutation (SNP) | VAF 40/260 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as rs372777278; called by muse, mutect2, varscan2
- ADAM28 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 38/309 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs779786372; called by muse, mutect2, varscan2
- ADAMTS12 | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 15/336 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as rs1381889273; called by muse, mutect2
- ADCY4 | c.1940A>G p.H647R | Missense Mutation (SNP) | VAF 71/407 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV104406596; called by muse, varscan2
- ADCY5 | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 99/515 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as rs368945449; called by muse, mutect2, varscan2
- ADCY7 | c.1480G>A p.A494T | Missense Mutation (SNP) | VAF 104/617 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.411); catalogued as COSV54266165; called by muse, mutect2, varscan2
- ADNP2 | c.242C>T p.S81F | Missense Mutation (SNP) | VAF 53/275 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51536849; called by muse, mutect2, varscan2
- ADRA2A | c.107del p.G36Afs*12 | Frame Shift Del (DEL) | VAF 100/452 reads (22%) | catalogued as rs1554870245; called by mutect2, varscan2
- AFDN | c.996G>A p.W332* | Nonsense Mutation (SNP) | VAF 26/225 reads (12%) | catalogued as COSV60045344; called by muse, mutect2, varscan2
- AFF4 | c.1358C>T p.A453V | Missense Mutation (SNP) | VAF 39/345 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.393); catalogued as rs1275254601; called by muse, mutect2, varscan2
- AKAP1 | c.216dup p.S73Qfs*41 | Frame Shift Ins (INS) | VAF 86/500 reads (17%) | catalogued as rs771272447; called by mutect2, pindel, varscan2
- AKAP17A | c.1271C>T p.A424V | Missense Mutation (SNP) | VAF 141/660 reads (21%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.91); catalogued as COSV100002507; called by muse, mutect2, varscan2
- AKAP17A | c.1861C>T p.R621W | Missense Mutation (SNP) | VAF 122/747 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.825); catalogued as rs758634437; called by muse, varscan2
- AKAP7 | c.236del p.K79Rfs*21 | Frame Shift Del (DEL) | VAF 54/265 reads (20%) | catalogued as rs763109484, COSV100818792; called by mutect2, varscan2
- AKAP9 | c.116del p.K39Rfs*17 | Frame Shift Del (DEL) | VAF 68/352 reads (19%) | catalogued as COSV62339755; called by mutect2, varscan2
- ALDH3A2 | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 32/264 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs763232206; called by muse, mutect2, varscan2
- ALKBH8 | c.1123G>A p.V375I | Missense Mutation (SNP) | VAF 63/367 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs908014696, COSV52834271; called by muse, mutect2, varscan2
- AMPD3 | c.1562C>T p.T521M (on ENST00000396553 / NM_001025389.2; = p.T530M on NM_000480.3) | Missense Mutation (SNP) | VAF 32/204 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs775155002; called by muse, mutect2, varscan2
- AMY2B | c.1204C>T p.R402* | Nonsense Mutation (SNP) | VAF 45/327 reads (14%) | catalogued as rs377067814, COSV63714132; called by muse, mutect2, varscan2
- ANK2 | c.11525G>A p.R3842Q | Missense Mutation (SNP) | VAF 68/427 reads (16%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.01); catalogued as rs770954138, COSV100003250, COSV52157432; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANK3 | c.11606C>T p.A3869V | Missense Mutation (SNP) | VAF 64/374 reads (17%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.991); catalogued as rs1351085518, COSV55062829; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.3767C>T p.T1256M | Missense Mutation (SNP) | VAF 27/172 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764045062; called by muse, mutect2, varscan2
- ANKRD31 | c.2778dup p.H927Tfs*3 | Frame Shift Ins (INS) | VAF 42/284 reads (15%) | catalogued as rs1373587337; called by mutect2, pindel, varscan2
- ANO1 | c.1955C>T p.A652V | Missense Mutation (SNP) | VAF 56/248 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV60285547; called by muse, varscan2
- ANO7 | c.1970T>C p.M657T (on ENST00000274979; = p.M603T on NM_001370694.2) | Missense Mutation (SNP) | VAF 62/306 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs1238381860; called by muse, mutect2, varscan2
- AP1M1 | c.601C>T p.R201* | Nonsense Mutation (SNP) | VAF 68/353 reads (19%) | catalogued as rs774557887; called by muse, mutect2, varscan2
- AP5B1 | c.1418C>T p.A473V | Missense Mutation (SNP) | VAF 108/563 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.253); catalogued as rs1277527085; called by muse, mutect2, varscan2
- API5 | c.1492+7G>A | Splice Region (SNP) | VAF 71/455 reads (16%) | catalogued as rs769164825; called by muse, mutect2, varscan2
- APOA4 | c.418G>A p.D140N | Missense Mutation (SNP) | VAF 126/569 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.02); catalogued as rs978473811; called by muse, mutect2, varscan2
- APOE | c.886G>A p.G296R | Missense Mutation (SNP) | VAF 107/536 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.703); catalogued as rs757764781, COSV52985043; called by muse, mutect2, varscan2
- ARAP3 | c.577A>G p.T193A | Missense Mutation (SNP) | VAF 66/361 reads (18%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as rs766627975; called by muse, mutect2, varscan2
- ARFGEF3 | c.1064del p.P355Hfs*11 | Frame Shift Del (DEL) | VAF 54/324 reads (17%) | catalogued as rs147530147; called by mutect2, varscan2
- ARFGEF3 | c.1969G>A p.A657T | Missense Mutation (SNP) | VAF 95/455 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.413); catalogued as rs774045707, COSV52455911; called by muse, mutect2, varscan2
- ARHGAP30 | c.1177C>T p.R393W | Missense Mutation (SNP) | VAF 106/600 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs765956977; called by muse, mutect2, varscan2
- ARHGAP45 | c.842del p.G281Afs*16 | Frame Shift Del (DEL) | VAF 92/532 reads (17%) | catalogued as COSV57429840; called by mutect2, pindel, varscan2
- ARHGEF1 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 49/354 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as rs370619761; called by muse, mutect2, varscan2
- ARHGEF11 | c.3727G>A p.V1243I | Missense Mutation (SNP) | VAF 88/430 reads (20%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as rs111558417, COSV59354403; called by muse, varscan2
- ARHGEF33 | c.2447del p.G816Afs*68 | Frame Shift Del (DEL) | VAF 55/376 reads (15%) | catalogued as rs1314040932; called by mutect2, pindel, varscan2
- ARID1A | c.5548del p.D1850Tfs*33 | Frame Shift Del (DEL) | VAF 77/501 reads (15%) | catalogued as COSV61389445; called by mutect2, pindel, varscan2
- ARMC2 | c.1514G>A p.R505H | Missense Mutation (SNP) | VAF 54/302 reads (18%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as rs777030964; called by muse, varscan2
- ASB1 | c.451G>A p.A151T | Missense Mutation (SNP) | VAF 58/383 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.271); catalogued as rs376136799; called by muse, mutect2, varscan2
- ASNSD1 | c.414dup p.G139Wfs*4 | Frame Shift Ins (INS) | VAF 52/311 reads (17%) | catalogued as rs759722534; called by mutect2, varscan2
- ATE1 | c.289del p.M97Cfs*2 | Frame Shift Del (DEL) | VAF 34/232 reads (15%) | catalogued as COSV56433777; called by mutect2, pindel, varscan2
- ATG9B | c.962del p.P321Rfs*4 | Frame Shift Del (DEL) | VAF 46/260 reads (18%) | catalogued as rs1563260326; called by mutect2, pindel, varscan2
- ATP4A | c.2543G>A p.R848H | Missense Mutation (SNP) | VAF 55/322 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs766761702; called by muse, mutect2, varscan2
- ATXN2 | c.2980G>A p.A994T (on ENST00000550104; = p.A834T on NM_002973.4) | Missense Mutation (SNP) | VAF 44/306 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.056); catalogued as rs1409495883; called by muse, varscan2
- BAZ1B | c.1018G>A p.V340I | Missense Mutation (SNP) | VAF 42/301 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.146); catalogued as rs781839851; called by muse, mutect2, varscan2
- BBX | c.2611A>G p.N871D (on ENST00000325805 / NM_001142568.3; = p.N841D on NM_020235.7) | Missense Mutation (SNP) | VAF 70/376 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs1367204164; called by muse, mutect2, varscan2
- BCKDK | c.250G>A p.G84S | Missense Mutation (SNP) | VAF 14/400 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.959); catalogued as rs1280171726; called by muse, mutect2
- BCO1 | c.1627G>A p.G543R | Missense Mutation (SNP) | VAF 42/231 reads (18%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.018); catalogued as rs752443339, COSV50731586; called by muse, mutect2, varscan2
- BCORL1 | c.3142C>T p.R1048* | Nonsense Mutation (SNP) | VAF 101/293 reads (34%) | catalogued as COSV54391404; called by muse, mutect2, varscan2
- BEGAIN | c.268C>T p.R90C | Missense Mutation (SNP) | VAF 48/313 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs140676218; called by muse, mutect2, varscan2
- BHLHE22 | c.451G>A p.D151N | Missense Mutation (SNP) | VAF 90/652 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.267); catalogued as rs914000580, COSV58861511; called by muse, varscan2
- BICRA | c.472G>T p.A158S | Missense Mutation (SNP) | VAF 98/546 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.772); catalogued as rs1410317356; called by mutect2, varscan2
- BLM | c.2268del p.D757Tfs*4 | Frame Shift Del (DEL) | VAF 30/245 reads (12%) | catalogued as rs747341586; called by mutect2, pindel, varscan2
- BLNK | c.527C>T p.A176V | Missense Mutation (SNP) | VAF 37/204 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs782568875; called by muse, mutect2, varscan2
- BMP2K | c.691G>T p.A231S | Missense Mutation (SNP) | VAF 29/170 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.878); catalogued as rs777127820; called by muse, mutect2, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 56/320 reads (18%) | catalogued as rs772920507, COSV65808737; called by mutect2, pindel, varscan2
- BMX | c.215C>T p.T72M | Missense Mutation (SNP) | VAF 48/129 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as rs774703027, COSV100564259, COSV100564556; called by muse, mutect2, varscan2
- BNC1 | c.225dup p.M76Hfs*17 | Frame Shift Ins (INS) | VAF 38/234 reads (16%) | catalogued as rs751941533; called by mutect2, varscan2
- BOC | c.2843C>T p.P948L | Missense Mutation (SNP) | VAF 66/365 reads (18%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as rs1338102608, COSV56355771; called by muse, mutect2, varscan2
- BPTF | c.5354C>T p.T1785M | Missense Mutation (SNP) | VAF 85/383 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.814); catalogued as rs202095865, COSV58835992; called by muse, mutect2, varscan2
- BRAP | c.173C>T p.A58V | Missense Mutation (SNP) | VAF 73/395 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as COSV58153818; called by muse, mutect2, varscan2
- BRD1 | c.2711C>T p.A904V (on ENST00000216267 / NM_001349940.1; = p.A1035V on NM_001304808.3) | Missense Mutation (SNP) | VAF 51/272 reads (19%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.991); catalogued as rs563026361, COSV53454922; called by muse, mutect2, varscan2
- BRINP2 | c.806G>A p.R269H | Missense Mutation (SNP) | VAF 39/278 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as rs199916624; called by muse, mutect2, varscan2
- C10orf71 | c.1429G>A p.G477R | Missense Mutation (SNP) | VAF 93/465 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); catalogued as rs141342139; called by muse, mutect2, varscan2
- C14orf28 | c.833A>G p.H278R | Missense Mutation (SNP) | VAF 60/315 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.895); catalogued as rs141946779; called by muse, varscan2
- C16orf54 | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 109/641 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.88); catalogued as rs1398580333; called by muse, mutect2, varscan2
- C1orf112 | c.756del p.F252Lfs*51 | Frame Shift Del (DEL) | VAF 39/338 reads (12%) | catalogued as rs1558068270; called by mutect2, pindel
- C2CD4C | c.250del p.R84Afs*21 | Frame Shift Del (DEL) | VAF 101/583 reads (17%) | catalogued as rs1360740103; called by mutect2, pindel, varscan2
- C2orf42 | c.98C>T p.T33I | Missense Mutation (SNP) | VAF 62/319 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.068); catalogued as rs1385053251; called by muse, mutect2, varscan2
- C4orf54 | c.4488del p.N1497Tfs*13 | Frame Shift Del (DEL) | VAF 61/452 reads (13%) | catalogued as rs1249107798; called by mutect2, pindel, varscan2
- C4orf54 | c.2338G>A p.G780R | Missense Mutation (SNP) | VAF 94/430 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1341324338; called by muse, mutect2, varscan2
- C4orf54 | c.990del p.G331Efs*45 | Frame Shift Del (DEL) | VAF 22/208 reads (11%) | catalogued as rs1388862189; called by mutect2, varscan2
- C7orf57 | c.506del p.K169Sfs*2 | Frame Shift Del (DEL) | VAF 41/203 reads (20%) | catalogued as rs747591930; called by mutect2, varscan2
- C9orf50 | c.170del p.G57Afs*87 | Frame Shift Del (DEL) | VAF 96/557 reads (17%) | catalogued as rs1423916757, COSV65252410; called by mutect2, varscan2
- C9orf78 | c.700G>A p.A234T | Missense Mutation (SNP) | VAF 53/309 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs758042858, COSV100989950; called by muse, mutect2, varscan2
- CACNA1A | c.4721C>T p.T1574M | Missense Mutation (SNP) | VAF 64/320 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.157); catalogued as rs767517315; called by muse, mutect2, varscan2
- CACNA1E | c.6152G>A p.R2051H (on ENST00000367573 / NM_001205293.3; = p.R2008H on NM_000721.4) | Missense Mutation (SNP) | VAF 44/302 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.009); catalogued as COSV62399825; called by muse, mutect2, varscan2
- CACNA1H | c.4444C>T p.R1482* | Nonsense Mutation (SNP) | VAF 60/351 reads (17%) | catalogued as rs763390819, COSV61991971; called by muse, mutect2, varscan2
- CACNA1I | c.2249G>A p.R750H | Missense Mutation (SNP) | VAF 78/491 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100359414; called by muse, mutect2, varscan2
- CALCRL | c.48del p.F16Lfs*2 | Frame Shift Del (DEL) | VAF 39/188 reads (21%) | catalogued as rs1486659949; called by mutect2, pindel, varscan2
- CALN1 | c.197G>A p.R66H (on ENST00000329008 / NM_001017440.3; = p.R108H on NM_031468.4) | Missense Mutation (SNP) | VAF 74/400 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs762029880, COSV100204904; called by muse, mutect2, varscan2
- CAPN15 | c.2941G>T p.G981C | Missense Mutation (SNP) | VAF 68/403 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54836374, COSV99562579; called by muse, mutect2, varscan2
- CASQ1 | c.225del p.E76Rfs*15 | Frame Shift Del (DEL) | VAF 70/329 reads (21%) | catalogued as rs766111752; called by mutect2, pindel, varscan2
- CBARP | c.1156G>A p.A386T (on ENST00000382477; = p.A366T on NM_152769.3) | Missense Mutation (SNP) | VAF 85/549 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs1003819494; called by muse, mutect2, varscan2
- CCDC168 | c.17627C>T p.A5876V | Missense Mutation (SNP) | VAF 87/469 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.141); catalogued as rs763329967, COSV59419932; called by muse, mutect2, varscan2
- CCDC178 | c.1863G>T p.K621N | Missense Mutation (SNP) | VAF 36/194 reads (19%) | SIFT tolerated (0.67); PolyPhen benign (0.006); catalogued as rs1300273325; called by muse, mutect2, varscan2
- CCDC178 | c.1279del p.T427Hfs*23 | Frame Shift Del (DEL) | VAF 22/236 reads (9%) | catalogued as rs776882105; called by mutect2, pindel
- CCDC43 | c.646del p.R216Gfs*20 | Frame Shift Del (DEL) | VAF 54/286 reads (19%) | catalogued as rs751135235; called by mutect2, varscan2
- CCDC88B | c.353del p.P118Qfs*61 | Frame Shift Del (DEL) | VAF 83/494 reads (17%) | catalogued as COSV57265375; called by mutect2, pindel, varscan2
- CCKBR | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 69/380 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1323044843, COSV100582861; called by muse, mutect2, varscan2
- CCR4 | c.993C>A p.Y331* | Nonsense Mutation (SNP) | VAF 62/316 reads (20%) | catalogued as rs1299019313, COSV100447462, COSV58381294, COSV58381335; called by muse, mutect2
- CCT8L2 | c.633del p.T212Hfs*11 | Frame Shift Del (DEL) | VAF 86/489 reads (18%) | catalogued as COSV63462859; called by mutect2, pindel, varscan2
- CD70 | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 61/420 reads (15%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs765737694, COSV55566532; called by muse, mutect2, varscan2
- CD79A | c.148G>A p.A50T | Missense Mutation (SNP) | VAF 71/364 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.751); catalogued as rs557160710; called by muse, mutect2, varscan2
- CDC73 | c.842G>A p.R281H | Missense Mutation (SNP) | VAF 44/254 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.358); catalogued as rs762716583, COSV66470275; called by muse, mutect2, varscan2
- CDH23 | c.5654G>A p.R1885H | Missense Mutation (SNP) | VAF 28/464 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs539839828; called by muse, mutect2
- CDK9 | c.627del p.I210Lfs*66 | Frame Shift Del (DEL) | VAF 73/400 reads (18%) | catalogued as rs755440676; called by mutect2, pindel, varscan2
- CELSR1 | c.1998del p.M667* | Frame Shift Del (DEL) | VAF 87/494 reads (18%) | catalogued as rs1471316712; called by mutect2, pindel, varscan2
- CELSR2 | c.3622C>T p.R1208C | Missense Mutation (SNP) | VAF 96/487 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs763539818; called by muse, mutect2, varscan2
- CELSR2 | c.5275C>T p.R1759W | Missense Mutation (SNP) | VAF 64/375 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as rs770117273, COSV54775898, COSV54779235; called by muse, mutect2, varscan2
- CEMIP2 | c.1156G>A p.V386M | Missense Mutation (SNP) | VAF 38/346 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.02); catalogued as rs748122995; called by muse, mutect2, varscan2
- CFAP46 | c.3523G>A p.E1175K | Missense Mutation (SNP) | VAF 66/374 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.27); catalogued as rs1323758376, COSV63952747; called by muse, mutect2, varscan2
- CFAP52 | c.1270G>A p.A424T | Missense Mutation (SNP) | VAF 62/374 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.967); catalogued as rs576284692, COSV100235573; called by muse, varscan2
- CHEK1 | c.1001A>G p.Y334C | Missense Mutation (SNP) | VAF 71/392 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.028); catalogued as rs781018582; called by muse, mutect2, varscan2
- CHPF2 | c.1972del p.A658Lfs*3 | Frame Shift Del (DEL) | VAF 75/468 reads (16%) | catalogued as rs756745837; called by mutect2, pindel, varscan2
- CHRM3 | c.1700del p.K567Rfs*31 | Frame Shift Del (DEL) | VAF 75/338 reads (22%) | catalogued as rs751548647; called by mutect2, varscan2
- CHRNG | c.127C>T p.P43S | Missense Mutation (SNP) | VAF 87/434 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51322994; called by muse, mutect2, varscan2
- CHST8 | c.1213G>A p.D405N | Missense Mutation (SNP) | VAF 65/454 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.416); catalogued as rs200926968; called by muse, mutect2, varscan2
- CILP2 | c.2989G>A p.G997R | Missense Mutation (SNP) | VAF 97/498 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759384337; called by muse, mutect2, varscan2
- CLSTN3 | c.2093C>T p.S698L | Missense Mutation (SNP) | VAF 36/328 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.024); catalogued as rs149690531; called by muse, mutect2, varscan2
- CLUH | c.3311C>T p.A1104V (on ENST00000435359; = p.A1143V on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/405 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1163727193, COSV70928491; called by muse, mutect2
- CMKLR1 | c.532C>T p.R178W (on ENST00000312143 / NM_001142344.2; = p.R176W on NM_004072.3) | Missense Mutation (SNP) | VAF 74/410 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs374245414; called by muse, varscan2
- CNGA4 | c.1181C>T p.A394V | Missense Mutation (SNP) | VAF 68/434 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV66006352; called by muse, mutect2, varscan2
- CNOT1 | c.83G>A p.S28N | Missense Mutation (SNP) | VAF 35/237 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.226); catalogued as COSV99069494; called by muse, mutect2, varscan2
- CNTNAP5 | c.2231G>A p.W744* | Nonsense Mutation (SNP) | VAF 33/217 reads (15%) | catalogued as COSV101444203; called by muse, mutect2, varscan2
- CNTNAP5 | c.2635G>A p.A879T | Missense Mutation (SNP) | VAF 63/353 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1376524715, COSV70514620; called by muse, mutect2, varscan2
- COG1 | c.1696G>A p.V566M | Missense Mutation (SNP) | VAF 73/498 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as rs146960628; called by muse, mutect2, varscan2
- COL11A1 | c.3285del p.G1096Vfs*102 | Frame Shift Del (DEL) | VAF 36/268 reads (13%) | catalogued as COSV62181107; called by mutect2, pindel, varscan2
- COL1A1 | c.1299C>T p.S433= | Splice Region (SNP) | VAF 78/359 reads (22%) | catalogued as rs776229611; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL3A1 | c.2866C>T p.R956W | Missense Mutation (SNP) | VAF 52/325 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs866738225; called by muse, mutect2, varscan2
- COL6A1 | c.2353G>A p.G785S | Missense Mutation (SNP) | VAF 69/378 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.414); catalogued as rs370546340, COSV62612426; called by muse, mutect2, varscan2
- CRACDL | c.1565del p.P522Rfs*182 | Frame Shift Del (DEL) | VAF 88/575 reads (15%) | catalogued as rs1414963793; called by mutect2, pindel, varscan2
- CREBBP | c.5921G>A p.R1974Q | Missense Mutation (SNP) | VAF 74/436 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.377); catalogued as rs769818976, COSV52126157; called by muse, mutect2, varscan2
- CRISPLD2 | c.1454G>A p.R485Q | Missense Mutation (SNP) | VAF 80/376 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as rs750379944, COSV52284727, COSV99295910; called by muse, mutect2, varscan2
- CRYBG3 | c.2957C>T p.A986V | Missense Mutation (SNP) | VAF 57/347 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.244); catalogued as rs909786691; called by muse, mutect2, varscan2
- CSF2RB | c.1701del p.S568Afs*130 | Frame Shift Del (DEL) | VAF 102/530 reads (19%) | catalogued as rs757082963; called by mutect2, varscan2
- CSMD1 | c.7751A>G p.Q2584R (on ENST00000520002; = p.Q2583R on NM_033225.6) | Missense Mutation (SNP) | VAF 64/377 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.136); catalogued as rs752993809; called by muse, varscan2
- CSMD3 | c.7149dup p.V2384Cfs*22 (on ENST00000297405 / NM_001363185.1; = p.V2280Cfs*22 on NM_052900.3) | Frame Shift Ins (INS) | VAF 28/296 reads (9%) | catalogued as rs1230860045; called by mutect2, pindel
- CSNK1A1 | c.601C>T p.R201* | Nonsense Mutation (SNP) | VAF 32/211 reads (15%) | catalogued as COSV55792773; called by muse, mutect2, varscan2
- CSPG4 | c.2969G>A p.R990H | Missense Mutation (SNP) | VAF 77/528 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as rs777862563, COSV57897206; called by muse, mutect2, varscan2
- CSPP1 | c.3635G>A p.G1212E (on ENST00000676605; = p.G1171E on NM_024790.6) | Missense Mutation (SNP) | VAF 61/398 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.22); catalogued as rs267601974; called by muse, mutect2, varscan2
- CTTN | c.962C>T p.A321V | Missense Mutation (SNP) | VAF 18/348 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745655495, COSV57231385; called by muse, mutect2
- CYB5R4 | c.741del p.E248Rfs*12 | Frame Shift Del (DEL) | VAF 30/189 reads (16%) | catalogued as rs745836350; called by mutect2, varscan2
- CYBB | c.1033G>A p.A345T | Missense Mutation (SNP) | VAF 70/299 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1307931082, COSV66085342; called by muse, mutect2, varscan2
- CYP11B2 | c.187C>G p.H63D | Missense Mutation (SNP) | VAF 27/598 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs61758594; called by muse, mutect2
- DAB2IP | c.3031G>A p.A1011T (on ENST00000408936; = p.A983T on NM_032552.3) | Missense Mutation (SNP) | VAF 53/373 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.104); catalogued as rs1041909484, COSV99404897; called by muse, mutect2, varscan2
- DBNDD2 | c.562del p.Q188Sfs*12 | Frame Shift Del (DEL) | VAF 84/474 reads (18%) | catalogued as rs1320987043; called by mutect2, pindel, varscan2
- DCAF1 | c.2762C>T p.A921V | Missense Mutation (SNP) | VAF 96/447 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as rs782798923; called by muse, mutect2, varscan2
- DCAF4L2 | c.1069C>A p.P357T | Missense Mutation (SNP) | VAF 101/534 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV60482611; called by muse, mutect2, varscan2
- DCLRE1A | c.1897C>T p.R633C | Missense Mutation (SNP) | VAF 46/291 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as rs138658617; called by muse, mutect2, varscan2
- DCP1A | c.999del p.S334Afs*8 | Frame Shift Del (DEL) | VAF 92/554 reads (17%) | catalogued as COSV99588276; called by mutect2, pindel, varscan2
- DDX23 | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 45/278 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.551); catalogued as rs774474991; called by muse, mutect2, varscan2
- DDX31 | c.914G>A p.G305D | Missense Mutation (SNP) | VAF 15/392 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1479960127, COSV60139815; called by muse, mutect2
- DDX3X | c.106C>T p.R36C (on ENST00000399959; = p.R37C on NM_001356.5) | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV67864090; called by muse, mutect2, varscan2
- DDX42 | c.2675G>A p.R892H | Missense Mutation (SNP) | VAF 65/356 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.06); catalogued as rs542105191, COSV63789397; called by muse, mutect2, varscan2
- DEDD | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 57/318 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200035776; called by muse, mutect2, varscan2
- DHDH | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 87/460 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.217); catalogued as rs377655210; called by muse, mutect2, varscan2
- DHDH | c.500G>A p.R167Q | Missense Mutation (SNP) | VAF 86/518 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.03); catalogued as rs546059210; called by muse, mutect2, varscan2
- DHX16 | c.2584G>A p.V862I | Missense Mutation (SNP) | VAF 107/582 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.155); catalogued as rs535573253; called by muse, mutect2, varscan2
- DHX29 | c.1387C>T p.R463* | Nonsense Mutation (SNP) | VAF 43/334 reads (13%) | catalogued as rs1379649782; called by muse, mutect2, varscan2
- DHX33 | c.1862G>A p.R621H | Missense Mutation (SNP) | VAF 65/351 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs150593794; called by muse, mutect2, varscan2
- DIAPH1 | c.2108del p.P703Hfs*65 | Frame Shift Del (DEL) | VAF 34/159 reads (21%) | catalogued as rs771360300; called by mutect2, varscan2
- DIP2A | c.1904C>T p.A635V | Missense Mutation (SNP) | VAF 41/227 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.392); catalogued as rs1450034201; called by muse, mutect2, varscan2
- DIRAS3 | c.337G>A p.V113I | Missense Mutation (SNP) | VAF 85/435 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.042); catalogued as COSV63970408; called by muse, mutect2, varscan2
- DISP2 | c.2918C>T p.A973V | Missense Mutation (SNP) | VAF 96/530 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.525); catalogued as rs556977731; called by muse, mutect2, varscan2
- DISP3 | c.2117G>A p.R706H | Missense Mutation (SNP) | VAF 79/447 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs768466757, COSV53835354; called by muse, mutect2, varscan2
- DLGAP1 | c.859C>T p.R287W | Missense Mutation (SNP) | VAF 83/441 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1455367831; called by muse, mutect2, varscan2
- DLGAP2 | c.393del p.R132Afs*15 | Frame Shift Del (DEL) | VAF 122/804 reads (15%) | catalogued as rs755665055, COSV101422687, COSV70099967; called by mutect2, varscan2
- DMRTA1 | c.277C>T p.R93W | Missense Mutation (SNP) | VAF 118/560 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100364945; called by muse, mutect2, varscan2
- DNAH3 | c.10556C>T p.A3519V | Missense Mutation (SNP) | VAF 56/298 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.091); catalogued as rs147867151; called by muse, mutect2, varscan2
- DNAH5 | c.6253C>A p.P2085T | Missense Mutation (SNP) | VAF 43/204 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54251521; called by muse, mutect2, varscan2
- DNAI4 | c.1660G>A p.V554I | Missense Mutation (SNP) | VAF 70/383 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.133); catalogued as rs375562160; called by muse, mutect2, varscan2
- DNAJC28 | c.642del p.G215Efs*13 | Frame Shift Del (DEL) | VAF 95/460 reads (21%) | catalogued as COSV58721733; called by mutect2, varscan2
- DNALI1 | c.550G>A p.A184T (on ENST00000296218; = p.A162T on NM_003462.5) | Missense Mutation (SNP) | VAF 74/461 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.111); catalogued as rs550154548, COSV99953525; called by muse, mutect2, varscan2
- DNMT1 | c.1885G>A p.D629N | Missense Mutation (SNP) | VAF 89/432 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as COSV61577970; called by muse, mutect2, varscan2
- DOK5 | c.712C>A p.L238I | Missense Mutation (SNP) | VAF 44/265 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.258); catalogued as rs928281731; called by muse, mutect2, varscan2
- DRAXIN | c.554C>T p.A185V | Missense Mutation (SNP) | VAF 91/406 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.628); catalogued as rs778134958; called by muse, mutect2, varscan2
- DRICH1 | c.436+1G>A p.X146_splice | Splice Site (SNP) | VAF 34/223 reads (15%) | catalogued as rs201474677, COSV58503613; called by muse, mutect2, varscan2
- DSP | c.7685_7687del p.S2562del | In Frame Del (DEL) | VAF 63/326 reads (19%) | catalogued as rs762495630; called by mutect2, pindel, varscan2
- DUSP4 | c.1072G>A p.A358T | Missense Mutation (SNP) | VAF 93/662 reads (14%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs749401971; called by muse, mutect2, varscan2
- DUSP8 | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 99/487 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.044); catalogued as rs1457400872; called by muse, mutect2, varscan2
- EAF2 | c.334del p.T112Qfs*30 | Frame Shift Del (DEL) | VAF 33/197 reads (17%) | catalogued as rs746509911; called by mutect2, varscan2
- EBF4 | c.259C>T p.R87C (on ENST00000609451; = p.R83C on NM_001110514.1) | Missense Mutation (SNP) | VAF 64/365 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1314768853; called by muse, mutect2, varscan2
- EDRF1 | c.3611C>T p.A1204V (on ENST00000356792 / NM_001202438.2; = p.A1170V on NM_015608.2) | Missense Mutation (SNP) | VAF 60/345 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.783); catalogued as COSV61762699; called by muse, mutect2, varscan2
- EGR1 | c.1000del p.H334Tfs*198 | Frame Shift Del (DEL) | VAF 73/507 reads (14%) | catalogued as rs746692720; called by mutect2, pindel, varscan2
- EIF3G | c.706G>A p.D236N | Missense Mutation (SNP) | VAF 33/283 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.926); catalogued as rs1238246473; called by muse, mutect2, varscan2
- EIF4G3 | c.421del p.T141Lfs*2 | Frame Shift Del (DEL) | VAF 28/226 reads (12%) | catalogued as rs1290746509; called by pindel, varscan2
- ELF4 | c.1021del p.Q341Rfs*30 | Frame Shift Del (DEL) | VAF 120/361 reads (33%) | catalogued as COSV57452819, COSV57454138; called by mutect2, pindel, varscan2
- EPHA1 | c.796C>T p.P266S | Missense Mutation (SNP) | VAF 71/407 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs768480626; called by muse, mutect2, varscan2
- EPHA6 | c.429G>T p.W143C | Missense Mutation (SNP) | VAF 41/242 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67593475; called by muse, mutect2, varscan2
- EPHB3 | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 54/310 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1237986709, COSV57807615, COSV57809863; called by muse, mutect2, varscan2
- EPHB4 | c.2484C>T p.D828= | Splice Region (SNP) | VAF 35/220 reads (16%) | catalogued as rs369079556; called by muse, mutect2, varscan2
- EPHX4 | c.1051T>C p.W351R | Missense Mutation (SNP) | VAF 41/236 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs201731090; called by muse, mutect2, varscan2
- EPN2 | c.1408del p.T470Qfs*5 | Frame Shift Del (DEL) | VAF 36/204 reads (18%) | catalogued as rs756461692; called by mutect2, varscan2
- ERBB2 | c.2153C>T p.T718M | Missense Mutation (SNP) | VAF 88/442 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV54076703; called by muse, mutect2, varscan2
- EVC2 | c.2479C>T p.R827C | Missense Mutation (SNP) | VAF 63/299 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.543); catalogued as rs373953980; called by muse, mutect2, varscan2
- EVPL | c.875G>A p.R292H | Missense Mutation (SNP) | VAF 96/454 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs756292666, COSV56908499; called by muse, mutect2, varscan2
- FAM117B | c.1027C>T p.R343W | Missense Mutation (SNP) | VAF 63/368 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs763647660; called by muse, mutect2, varscan2
- FAM149B1 | c.243A>G p.I81M | Missense Mutation (SNP) | VAF 37/236 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.293); catalogued as rs1253361920; called by muse, mutect2, varscan2
- FAM181B | c.339del p.G114Afs*80 | Frame Shift Del (DEL) | VAF 48/318 reads (15%) | catalogued as rs1555002816, COSV100235053; called by mutect2, pindel, varscan2
- FAM184B | c.2051G>A p.R684H | Missense Mutation (SNP) | VAF 47/254 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs1260136713, COSV99401150; called by muse, mutect2, varscan2
- FAM210B | c.371A>G p.D124G | Missense Mutation (SNP) | VAF 39/273 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100452722; called by muse, mutect2, varscan2
- FAM222B | c.227G>A p.R76H | Missense Mutation (SNP) | VAF 91/528 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs749632669; called by muse, mutect2, varscan2
- FAM47C | c.1460G>A p.R487H | Missense Mutation (SNP) | VAF 36/275 reads (13%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.115); catalogued as rs782001583, COSV63726534; called by muse, mutect2, varscan2
- FAM83H | c.10C>T p.R4C | Missense Mutation (SNP) | VAF 40/584 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs782116903; called by muse, mutect2
- FANCA | c.2558G>A p.R853Q | Missense Mutation (SNP) | VAF 52/298 reads (17%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs753393669, COSV59796005; called by muse, mutect2, varscan2
- FAT3 | c.11350C>T p.R3784C | Missense Mutation (SNP) | VAF 36/237 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.939); catalogued as COSV53118639; called by muse, mutect2, varscan2
- FAT4 | c.818C>T p.A273V | Missense Mutation (SNP) | VAF 96/491 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.215); catalogued as COSV67880909; called by muse, mutect2, varscan2
- FAT4 | c.12098C>T p.A4033V | Missense Mutation (SNP) | VAF 64/389 reads (16%) | SIFT tolerated (1); PolyPhen probably damaging (0.968); catalogued as COSV58683483; called by muse, mutect2, varscan2
- FBLN1 | c.1657G>A p.A553T | Missense Mutation (SNP) | VAF 54/332 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.13); catalogued as rs1158899800; called by muse, mutect2, varscan2
- FBXL2 | c.200G>A p.R67Q | Missense Mutation (SNP) | VAF 40/265 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs747950097; called by muse, mutect2, varscan2
- FBXW7 | c.1817G>A p.W606* (on ENST00000281708 / NM_001349798.2; = p.W526* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 43/252 reads (17%) | catalogued as COSV55891137, COSV55897699, COSV55912557; called by muse, mutect2, varscan2
- FBXW9 | c.398C>A p.P133Q (on ENST00000587955; = p.P143Q on NM_032301.3) | Missense Mutation (SNP) | VAF 68/331 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as rs754626651; called by muse, mutect2, varscan2
- FCRL3 | c.800A>G p.H267R | Missense Mutation (SNP) | VAF 48/282 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.105); catalogued as rs745560678; called by muse, varscan2
- FES | c.460C>T p.R154C | Missense Mutation (SNP) | VAF 51/303 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs763723341, COSV51576613; called by muse, mutect2, varscan2
- FGF18 | c.472C>T p.R158W | Missense Mutation (SNP) | VAF 46/436 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as COSV51125236; called by muse, mutect2, varscan2
- FGFR2 | c.1165G>A p.A389T | Missense Mutation (SNP) | VAF 56/308 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs781714766, COSV60641778; called by muse, mutect2, varscan2
- FIZ1 | c.1019C>T p.A340V | Missense Mutation (SNP) | VAF 128/636 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV99684581; called by muse, mutect2, varscan2
- FKBP15 | c.2143C>T p.R715W | Missense Mutation (SNP) | VAF 72/371 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs961188094; called by muse, mutect2, varscan2
- FOLH1 | c.1526T>C p.M509T | Missense Mutation (SNP) | VAF 45/220 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1193893649; called by muse, mutect2, varscan2
- FOLR1 | c.677C>T p.A226V | Missense Mutation (SNP) | VAF 70/454 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.604); catalogued as rs371399726, COSV100398516; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FOXJ2 | c.917A>C p.Q306P | Missense Mutation (SNP) | VAF 115/578 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs745407957, COSV99368130; called by muse, varscan2
- FRAS1 | c.8513C>T p.T2838M | Missense Mutation (SNP) | VAF 61/360 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs776331026; called by muse, mutect2, varscan2
- FXR2 | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 72/321 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as rs1011830446; called by muse, mutect2, varscan2
- GAB2 | c.1882C>T p.R628C (on ENST00000361507 / NM_080491.3; = p.R590C on NM_012296.3) | Missense Mutation (SNP) | VAF 46/302 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs374012460; called by muse, mutect2, varscan2
- GAD2 | c.343A>G p.M115V | Missense Mutation (SNP) | VAF 58/344 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1265720771; called by muse, mutect2, varscan2
- GALNT17 | c.127C>T p.R43W | Missense Mutation (SNP) | VAF 74/510 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.232); catalogued as rs778395109, COSV61168313; called by muse, mutect2, varscan2
- GBP6 | c.1478C>T p.A493V | Missense Mutation (SNP) | VAF 32/246 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.232); catalogued as COSV100969425; called by muse, mutect2, varscan2
- GDE1 | c.373C>T p.R125* | Nonsense Mutation (SNP) | VAF 69/394 reads (18%) | catalogued as rs777419553, COSV62059371; called by muse, mutect2, varscan2
- GIPC3 | c.4045C>G p.P1349A | Missense Mutation (SNP) | VAF 61/361 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.737); catalogued as rs952242405; called by muse, mutect2, varscan2
- GIT2 | c.1921G>A p.E641K (on ENST00000355312 / NM_057169.5; = p.E563K on NM_014776.5) | Missense Mutation (SNP) | VAF 71/432 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs754246516, COSV104405673; called by muse, mutect2, varscan2
- GLCCI1 | c.665C>T p.A222V | Missense Mutation (SNP) | VAF 24/174 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs777220141, COSV99779982; called by muse, varscan2
- GLDC | c.692C>T p.A231V | Missense Mutation (SNP) | VAF 39/328 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.928); catalogued as COSV100394537; called by muse, mutect2, varscan2
- GMIP | c.792G>A p.A264= | Splice Region (SNP) | VAF 70/433 reads (16%) | catalogued as rs778149370; called by muse, mutect2, varscan2
- GNA15 | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 48/280 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199847220; called by muse, mutect2, varscan2
- GOLGA6L6 | c.1501C>T p.R501W | Missense Mutation (SNP) | VAF 59/296 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1230580971, COSV101417052, COSV71180979; called by muse, mutect2, varscan2
- GOT1L1 | c.1243del p.T415Hfs*2 | Frame Shift Del (DEL) | VAF 70/274 reads (26%) | catalogued as rs370114090; called by mutect2, varscan2
- GPATCH8 | c.289C>T p.R97W | Missense Mutation (SNP) | VAF 52/262 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as rs1250210549, COSV59200349; called by muse, mutect2, varscan2
- GPCPD1 | c.1537C>T p.R513W | Missense Mutation (SNP) | VAF 37/202 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770440181, COSV66830643; called by muse, mutect2, varscan2
- GPR142 | c.1353G>A p.M451I | Missense Mutation (SNP) | VAF 16/374 reads (4%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs1352840541, COSV59518730; called by muse, mutect2
- GPR176 | c.203G>A p.R68H | Missense Mutation (SNP) | VAF 61/286 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs377756503, COSV54447202; called by muse, varscan2
- GREB1 | c.3120G>A p.P1040= | Splice Region (SNP) | VAF 42/201 reads (21%) | catalogued as rs762653939; called by muse, mutect2, varscan2
- GRHL1 | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 51/280 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs777578383, COSV61408217; called by muse, mutect2, varscan2
- GRIK2 | c.518C>T p.T173M | Missense Mutation (SNP) | VAF 28/244 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753387479, COSV59747466; called by muse, mutect2, varscan2
- GRIK3 | c.2491G>A p.G831R | Missense Mutation (SNP) | VAF 87/551 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV66135794; called by muse, mutect2, varscan2
- GRIN2A | c.4355G>A p.R1452H | Missense Mutation (SNP) | VAF 65/310 reads (21%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.998); catalogued as rs774039446, COSV58020621; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GRM1 | c.2335G>A p.A779T | Missense Mutation (SNP) | VAF 82/451 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs745330594, COSV51120808; called by muse, mutect2, varscan2
- GTDC1 | c.680G>A p.G227D | Missense Mutation (SNP) | VAF 57/304 reads (19%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as rs573539615, COSV99602330; called by muse, mutect2, varscan2
- GTF3C1 | c.2299del p.S767Vfs*7 | Frame Shift Del (DEL) | VAF 61/357 reads (17%) | catalogued as rs1231771183; called by mutect2, pindel, varscan2
- GTF3C4 | c.1964C>T p.T655M | Missense Mutation (SNP) | VAF 87/415 reads (21%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs777246101; called by muse, mutect2, varscan2
- H6PD | c.787G>A p.V263I | Missense Mutation (SNP) | VAF 74/388 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.296); catalogued as rs767129218, COSV66231480; called by muse, mutect2, varscan2
- HACE1 | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.946); catalogued as rs147905940; called by muse, mutect2, varscan2
- HAS2 | c.515C>T p.T172M | Missense Mutation (SNP) | VAF 50/496 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.06); catalogued as rs747190006, COSV100391400; called by muse, mutect2, varscan2
- HCFC1R1 | c.249del p.M84* | Frame Shift Del (DEL) | VAF 77/381 reads (20%) | catalogued as rs746547303; called by mutect2, pindel, varscan2
- HDAC1 | c.1402_1404del p.E468del | In Frame Del (DEL) | VAF 46/370 reads (12%) | catalogued as rs771427696; called by pindel, varscan2
- HERC2 | c.7379C>T p.P2460L | Missense Mutation (SNP) | VAF 56/356 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as rs764510642; called by muse, mutect2, varscan2
- HERC2 | c.554C>T p.A185V | Missense Mutation (SNP) | VAF 71/408 reads (17%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs769828970, COSV55327128; called by muse, mutect2, varscan2
- HEXD | c.565C>T p.R189C | Missense Mutation (SNP) | VAF 80/494 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as rs777599293; called by muse, mutect2, varscan2
- HFM1 | c.4200del p.F1400Lfs*25 | Frame Shift Del (DEL) | VAF 23/238 reads (10%) | catalogued as rs766204131; called by pindel, varscan2*
- HIP1R | c.1591G>A p.A531T | Missense Mutation (SNP) | VAF 95/471 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs772737932, COSV99459545; called by muse, mutect2, varscan2
- HIVEP3 | c.1270C>T p.R424* | Nonsense Mutation (SNP) | VAF 75/408 reads (18%) | catalogued as COSV56009059; called by muse, mutect2, varscan2
- HK2 | c.1261C>T p.P421S | Missense Mutation (SNP) | VAF 43/254 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs1412550199; called by muse, mutect2, varscan2
- HMCN1 | c.8926G>A p.V2976I | Missense Mutation (SNP) | VAF 46/271 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs772967670, COSV54884035; called by muse, mutect2, varscan2
- HMMR | c.1175A>G p.E392G | Missense Mutation (SNP) | VAF 63/324 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs779096646; called by muse, mutect2, varscan2
- HNF4G | c.121C>T p.R41C (on ENST00000354370 / NM_001330561.2; = p.R88C on NM_004133.5) | Missense Mutation (SNP) | VAF 54/356 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62966093; called by muse, mutect2, varscan2
- HOXA1 | c.146G>A p.G49D | Missense Mutation (SNP) | VAF 107/506 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.08); catalogued as COSV56065775, COSV56067593; called by muse, varscan2
- HOXC12 | c.317del p.G106Afs*2 | Frame Shift Del (DEL) | VAF 90/594 reads (15%) | catalogued as COSV99678820; called by mutect2, pindel, varscan2
- HS3ST4 | c.358G>A p.A120T | Missense Mutation (SNP) | VAF 92/530 reads (17%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs757020908; called by muse, mutect2, varscan2
- HSPA1L | c.1076G>A p.R359H | Missense Mutation (SNP) | VAF 70/401 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.888); catalogued as rs1036938945; called by muse, mutect2, varscan2
- HUWE1 | c.13000C>T p.R4334C | Missense Mutation (SNP) | VAF 59/172 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99470919; called by muse, mutect2, varscan2
- HVCN1 | c.689G>T p.R230M | Missense Mutation (SNP) | VAF 24/182 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV99657501; called by mutect2, varscan2
- IBTK | c.2912+1G>A p.X971_splice | Splice Site (SNP) | VAF 18/126 reads (14%) | catalogued as rs1035592414; called by muse, varscan2
- IFNAR2 | c.1209G>T p.Q403H | Missense Mutation (SNP) | VAF 86/433 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.753); catalogued as COSV99269707; called by muse, mutect2, varscan2
- IFNL3 | c.287C>A p.A96D | Missense Mutation (SNP) | VAF 52/392 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV69830119; called by muse, mutect2, varscan2
- IGHV1-3 | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.067); catalogued as rs1333699560; called by muse, mutect2
- IGSF5 | c.88G>A p.A30T | Missense Mutation (SNP) | VAF 41/234 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs1374529392; called by muse, mutect2, varscan2
- IGSF8 | c.326C>T p.A109V | Missense Mutation (SNP) | VAF 73/457 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.174); catalogued as COSV58757715; called by muse, mutect2, varscan2
- IGSF9 | c.928C>T p.P310S | Missense Mutation (SNP) | VAF 78/436 reads (18%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.721); catalogued as COSV100829633; called by muse, mutect2, varscan2
- IKZF4 | c.1144C>T p.R382C | Missense Mutation (SNP) | VAF 85/384 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV56267300; called by muse, mutect2, varscan2
- IL17RD | c.1096G>A p.D366N | Missense Mutation (SNP) | VAF 67/384 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV56341000; called by muse, mutect2, varscan2
- IL17REL | c.118C>T p.R40W | Missense Mutation (SNP) | VAF 71/352 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as rs182975550, COSV58008473; called by muse, mutect2, varscan2
- IL2RG | c.1082del p.P361Hfs*5 | Frame Shift Del (DEL) | VAF 94/268 reads (35%) | catalogued as rs745545309; called by mutect2, pindel, varscan2
- INTS9 | c.1531C>T p.R511C | Missense Mutation (SNP) | VAF 64/439 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs199718736; called by muse, mutect2, varscan2
- IPO9 | c.2326C>T p.R776W | Missense Mutation (SNP) | VAF 68/404 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.316); catalogued as rs766537773; called by muse, mutect2, varscan2
- IQCA1L | c.1852C>T p.R618* | Nonsense Mutation (SNP) | VAF 49/277 reads (18%) | catalogued as rs1170786689; called by muse, mutect2, varscan2
- IRF4 | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 72/360 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1459743512, COSV101110804, COSV66704417; called by muse, mutect2, varscan2
- IRS2 | c.3924del p.P1309Rfs*22 | Frame Shift Del (DEL) | VAF 75/534 reads (14%) | catalogued as rs747968639; called by pindel, varscan2
- ISG20L2 | c.865dup p.L289Pfs*6 | Frame Shift Ins (INS) | VAF 58/358 reads (16%) | catalogued as rs761558950; called by mutect2, varscan2
- ITGA7 | c.3038G>A p.R1013H (on ENST00000555728; = p.R969H on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 65/318 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs762923857, COSV57700601; called by muse, mutect2, varscan2
- ITGAV | c.57_59del p.L20del | In Frame Del (DEL) | VAF 68/451 reads (15%) | catalogued as rs748650488; called by pindel, varscan2
- ITGB4 | c.1342G>A p.A448T | Missense Mutation (SNP) | VAF 63/368 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.04); catalogued as rs371466417; called by muse, mutect2, varscan2
- ITGB8 | c.27dup p.T10Yfs*34 | Frame Shift Ins (INS) | VAF 68/365 reads (19%) | catalogued as rs760028800; called by mutect2, varscan2
- ITM2B | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 37/227 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.061); catalogued as rs756025247, COSV101052317; called by muse, mutect2, varscan2
- JAK1 | c.1289del p.P430Rfs*2 | Frame Shift Del (DEL) | VAF 68/336 reads (20%) | catalogued as rs755650243; called by mutect2, varscan2
- JARID2 | c.1272dup p.R425Afs*99 | Frame Shift Ins (INS) | VAF 57/358 reads (16%) | catalogued as rs747291227; called by mutect2, varscan2
- KANSL1 | c.611del p.G204Vfs*2 | Frame Shift Del (DEL) | VAF 87/697 reads (12%) | catalogued as rs1304078301; called by mutect2, pindel, varscan2
- KAT6A | c.4915G>A p.V1639M | Missense Mutation (SNP) | VAF 112/749 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs757043455, COSV55902382; called by muse, mutect2, varscan2
- KBTBD2 | c.287T>C p.M96T | Missense Mutation (SNP) | VAF 58/346 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs982383887; called by muse, mutect2, varscan2
- KBTBD6 | c.1109C>T p.P370L | Missense Mutation (SNP) | VAF 88/412 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.284); catalogued as COSV65271062; called by muse, mutect2, varscan2
- KCNA5 | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 48/524 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as rs1555100213, COSV99363588; called by muse, mutect2
- KCNA5 | c.989C>T p.T330M | Missense Mutation (SNP) | VAF 78/498 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.49); catalogued as rs746186154, COSV52906373; called by muse, mutect2, varscan2
- KCNF1 | c.1103T>C p.M368T | Missense Mutation (SNP) | VAF 91/480 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs987877881; called by muse, mutect2, varscan2
- KCNG3 | c.173G>A p.R58H | Missense Mutation (SNP) | VAF 110/503 reads (22%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); catalogued as COSV60148778; called by muse, mutect2, varscan2
- KCNG4 | c.1018C>T p.R340* | Nonsense Mutation (SNP) | VAF 96/468 reads (21%) | catalogued as rs371318548; called by muse, mutect2, varscan2
- KCNH3 | c.2491G>A p.G831S | Missense Mutation (SNP) | VAF 60/310 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.125); catalogued as rs749608521; called by muse, mutect2, varscan2
- KCNH4 | c.642dup p.S215Vfs*39 | Frame Shift Ins (INS) | VAF 48/344 reads (14%) | catalogued as rs753954093; called by mutect2, varscan2
- KCTD12 | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 100/523 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100499664; called by muse, mutect2, varscan2
- KDM5B | c.83C>A p.P28H | Missense Mutation (SNP) | VAF 115/582 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV99351341; called by muse, mutect2, varscan2
- KHDRBS1 | c.267dup p.S90Lfs*41 | Frame Shift Ins (INS) | VAF 110/672 reads (16%) | catalogued as rs1258549955; called by mutect2, pindel, varscan2
- KIAA0232 | c.469C>T p.P157S | Missense Mutation (SNP) | VAF 33/294 reads (11%) | SIFT tolerated (0.65); PolyPhen benign (0.26); catalogued as rs1210399666, COSV56923255; called by muse, mutect2, varscan2
- KIAA0319 | c.29C>G p.S10* | Nonsense Mutation (SNP) | VAF 57/306 reads (19%) | catalogued as COSV100985560, COSV65501265; called by muse, mutect2, varscan2
- KIAA0825 | c.3590C>T p.A1197V | Missense Mutation (SNP) | VAF 41/254 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs528412872; called by muse, varscan2
- KIAA1109 | c.4849G>A p.A1617T | Missense Mutation (SNP) | VAF 19/352 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.211); catalogued as rs1418863940; called by muse, mutect2
- KIAA2012 | c.1543del p.S515Vfs*25 | Frame Shift Del (DEL) | VAF 35/261 reads (13%) | catalogued as COSV99863055; called by mutect2, varscan2
- KIF1B | c.1000G>A p.A334T (on ENST00000377086 / NM_001365952.1; = p.A328T on NM_015074.3) | Missense Mutation (SNP) | VAF 55/280 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs761570473; called by muse, mutect2, varscan2
- KLF14 | c.394G>A p.A132T | Missense Mutation (SNP) | VAF 130/720 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as rs782462856; called by muse, mutect2
- KLF2 | c.503del p.P168Rfs*122 | Frame Shift Del (DEL) | VAF 70/355 reads (20%) | catalogued as rs1568375323; called by mutect2, pindel, varscan2
- KLF5 | c.910C>T p.P304S | Missense Mutation (SNP) | VAF 82/452 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66614466, COSV66615085; called by muse, mutect2, varscan2
- KMT2B | c.4525G>A p.D1509N | Missense Mutation (SNP) | VAF 62/293 reads (21%) | SIFT tolerated (0.6); PolyPhen benign (0.23); catalogued as rs1026487026; called by muse, mutect2, varscan2
- KMT2D | c.12307C>T p.Q4103* | Nonsense Mutation (SNP) | VAF 91/522 reads (17%) | catalogued as CM158167; called by muse, mutect2, varscan2
- KMT2D | c.7202G>A p.R2401H | Missense Mutation (SNP) | VAF 76/612 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.813); catalogued as rs375115132; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KNDC1 | c.2354C>T p.P785L | Missense Mutation (SNP) | VAF 107/628 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs370595982; called by muse, mutect2, varscan2
- KPTN | c.273del p.K92Sfs*22 | Frame Shift Del (DEL) | VAF 86/428 reads (20%) | catalogued as COSV99645797; called by mutect2, pindel, varscan2
- KRT26 | c.875A>G p.H292R | Missense Mutation (SNP) | VAF 69/316 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.088); catalogued as rs1286112736; called by muse, mutect2, varscan2
- KRT72 | c.287del p.G96Afs*37 | Frame Shift Del (DEL) | VAF 84/513 reads (16%) | catalogued as rs754302246; called by mutect2, pindel, varscan2
- KSR1 | c.842C>T p.T281I (on ENST00000644974 / NM_001367810.1; = p.T144I on NM_014238.2) | Missense Mutation (SNP) | VAF 64/396 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.056); catalogued as COSV52028479, COSV52029332; called by muse, varscan2
- LACTB | c.662G>A p.R221H | Missense Mutation (SNP) | VAF 22/197 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs142422927; called by muse, mutect2, varscan2
- LAMA3 | c.782G>A p.R261H | Missense Mutation (SNP) | VAF 61/325 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as rs777581271, COSV58070038; called by muse, mutect2, varscan2
- LAMTOR5 | c.101G>A p.R34H (on ENST00000602318 / NM_001382293.1; = p.R116H on NM_006402.3) | Missense Mutation (SNP) | VAF 29/228 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs766029896, COSV56679574; called by muse, mutect2, varscan2
- LGR5 | c.2182G>A p.A728T | Missense Mutation (SNP) | VAF 71/385 reads (18%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.472); catalogued as rs749746712, COSV57007659; called by muse, mutect2, varscan2
- LHFPL5 | c.472C>T p.R158W | Missense Mutation (SNP) | VAF 82/427 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs753739358, CM161008, COSV64178052; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LIFR | c.2579G>A p.R860Q | Missense Mutation (SNP) | VAF 40/214 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.166); catalogued as rs765499626, COSV54692351; called by muse, mutect2, varscan2
- LMAN1 | c.912del p.E305Rfs*22 | Frame Shift Del (DEL) | VAF 67/308 reads (22%) | catalogued as rs746845401, CD099553; called by mutect2, varscan2
- LMOD3 | c.1483C>T p.R495C | Missense Mutation (SNP) | VAF 81/529 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs749726841, COSV101341961; called by muse, mutect2, varscan2
- LONP1 | c.2488C>T p.P830S | Missense Mutation (SNP) | VAF 79/475 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs1484060909; called by muse, mutect2, varscan2
- LONP1 | c.1615G>A p.A539T | Missense Mutation (SNP) | VAF 87/473 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1250280079, COSV62263483; called by muse, mutect2, varscan2
- LRIG3 | c.1891G>A p.A631T | Missense Mutation (SNP) | VAF 87/511 reads (17%) | SIFT tolerated (0.56); PolyPhen benign (0.027); catalogued as rs1243163876; called by muse, mutect2, varscan2
- LRP1 | c.12575del p.P4192Qfs*150 | Frame Shift Del (DEL) | VAF 46/350 reads (13%) | catalogued as rs757410385; called by mutect2, varscan2
- LRP2 | c.8254C>T p.R2752* | Nonsense Mutation (SNP) | VAF 60/308 reads (19%) | catalogued as COSV55542953; called by muse, mutect2, varscan2
- LRP5 | c.2989C>T p.R997C | Missense Mutation (SNP) | VAF 62/327 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as rs926783835; called by muse, mutect2, varscan2
- LRRC7 | c.2720G>T p.S907I (on ENST00000651989 / NM_001370785.2; = p.S874I on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 67/399 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV50416112; called by muse, mutect2, varscan2
- LRRD1 | c.418G>A p.G140R | Missense Mutation (SNP) | VAF 44/321 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs922085762; called by muse, mutect2, varscan2
- LY6L | c.72A>G p.P24= | Splice Region (SNP) | VAF 101/597 reads (17%) | catalogued as rs1252535020; called by muse, mutect2, varscan2
- LZIC | c.570dup p.*191Mfs*8 | Frame Shift Ins (INS) | VAF 49/212 reads (23%) | catalogued as rs753028254; called by mutect2, varscan2
- MAFG | c.221C>T p.T74M | Missense Mutation (SNP) | VAF 74/480 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); catalogued as rs772766552, COSV100155458; called by muse, mutect2, varscan2
- MAGEA6 | c.563G>A p.G188D | Missense Mutation (SNP) | VAF 91/257 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV61449424; called by muse, mutect2, varscan2
- MAGEB6 | c.44G>A p.R15H | Missense Mutation (SNP) | VAF 52/165 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.82); catalogued as rs750398271, COSV100983679, COSV66872128; called by muse, mutect2, varscan2
- MAGI1 | c.2893G>A p.V965M (on ENST00000402939 / NM_001033057.2; = p.V993M on NM_004742.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 100/573 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.852); catalogued as rs928574212, COSV100442778; called by muse, mutect2, varscan2
- MAGI1 | c.2257C>T p.R753* | Nonsense Mutation (SNP) | VAF 37/394 reads (9%) | catalogued as rs780637413, COSV58317755; called by muse, mutect2
- MAGI1 | c.590T>A p.V197D | Missense Mutation (SNP) | VAF 52/333 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.137); catalogued as rs1331514262; called by muse, mutect2, varscan2
- MAGI2 | c.104del p.G35Afs*13 | Frame Shift Del (DEL) | VAF 76/461 reads (16%) | catalogued as COSV62634980; called by mutect2, varscan2
- MAN2A2 | c.3115C>T p.R1039C | Missense Mutation (SNP) | VAF 92/423 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.773); catalogued as rs570702789; called by muse, mutect2, varscan2
- MAN2B1 | c.2515C>T p.R839* | Nonsense Mutation (SNP) | VAF 117/584 reads (20%) | catalogued as rs1291147781, CM124069; called by muse, mutect2, varscan2
- MAP3K10 | c.2521G>A p.E841K | Missense Mutation (SNP) | VAF 82/401 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.107); catalogued as rs1238271164; called by muse, mutect2, varscan2
- MAP3K21 | c.1169C>T p.S390L | Missense Mutation (SNP) | VAF 62/300 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.581); catalogued as rs753079246, COSV64045846; called by muse, mutect2, varscan2
- MAPK8IP3 | c.656G>A p.R219H | Missense Mutation (SNP) | VAF 44/634 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.964); catalogued as rs201393775, COSV51719654; called by muse, mutect2
- MARS1 | c.1201G>A p.V401M | Missense Mutation (SNP) | VAF 50/375 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774447812, COSV56258270; called by muse, mutect2, varscan2
- MCM3AP | c.4371G>A p.M1457I | Missense Mutation (SNP) | VAF 79/444 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52442383; called by muse, mutect2, varscan2
- MDGA2 | c.49C>T p.R17W | Missense Mutation (SNP) | VAF 64/480 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.833); catalogued as COSV67813150; called by mutect2, varscan2
- MDN1 | c.13826G>A p.R4609H | Missense Mutation (SNP) | VAF 52/311 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs749751064; called by muse, mutect2, varscan2
- MED15 | c.1357del p.Q453Sfs*41 (on ENST00000263205 / NM_001003891.3; = p.Q413Sfs*41 on NM_015889.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 49/324 reads (15%) | catalogued as COSV99487865; called by mutect2, pindel, varscan2
- MED16 | c.1348G>A p.G450R | Missense Mutation (SNP) | VAF 55/290 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765012844; called by muse, mutect2, varscan2
- MED17 | c.1075A>G p.T359A | Missense Mutation (SNP) | VAF 46/260 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.023); catalogued as rs139951951; called by muse, mutect2, varscan2
- MED25 | c.1606G>A p.G536S | Missense Mutation (SNP) | VAF 87/459 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.921); catalogued as rs1386644663; called by muse, mutect2, varscan2
- METTL24 | c.1052A>T p.N351I | Missense Mutation (SNP) | VAF 36/245 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99080824; called by muse, mutect2, varscan2
- METTL7A | c.103T>C p.W35R | Missense Mutation (SNP) | VAF 68/418 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.065); catalogued as rs1166805719; called by muse, mutect2, varscan2
- MEX3D | c.1450G>A p.A484T | Missense Mutation (SNP) | VAF 105/652 reads (16%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.096); catalogued as rs751641597; called by muse, mutect2, varscan2
- MIDEAS | c.2644C>T p.R882C | Missense Mutation (SNP) | VAF 59/318 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750826331; called by muse, mutect2, varscan2
- MIDN | c.977C>T p.S326L | Missense Mutation (SNP) | VAF 19/701 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as rs1418165624, COSV99960226; called by muse, mutect2
- MKX | c.833G>A p.R278H | Missense Mutation (SNP) | VAF 41/234 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs760287864, COSV65392386; called by muse, mutect2, varscan2
- MMD2 | c.13del p.R5Gfs*14 | Frame Shift Del (DEL) | VAF 40/278 reads (14%) | catalogued as rs1261389981, COSV68661014; called by mutect2, pindel, varscan2
- MMP9 | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 64/433 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.902); catalogued as rs1262533864; called by muse, mutect2, varscan2
- MN1 | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 96/551 reads (17%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); catalogued as COSV56559991; called by muse, varscan2
- MNDA | c.643G>A p.V215M | Missense Mutation (SNP) | VAF 68/357 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV63741284; called by muse, mutect2, varscan2
- MOB2 | c.182del p.F61Sfs*52 | Frame Shift Del (DEL) | VAF 31/270 reads (11%) | catalogued as COSV57319526; called by mutect2, pindel, varscan2
- MRC2 | c.3583C>T p.R1195W | Missense Mutation (SNP) | VAF 61/389 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as rs1446902653; called by muse, mutect2, varscan2
- MRPL55 | c.148C>T p.R50* | Nonsense Mutation (SNP) | VAF 84/464 reads (18%) | catalogued as rs759317636, COSV54342482; called by muse, mutect2, varscan2
- MRPS10 | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 74/409 reads (18%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.003); catalogued as rs548348475, COSV99273495; called by muse, mutect2, varscan2
- MSR1 | c.652C>T p.R218C | Missense Mutation (SNP) | VAF 28/213 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.732); catalogued as rs770076920; called by muse, varscan2
- MSTO1 | c.925C>T p.R309* | Nonsense Mutation (SNP) | VAF 72/366 reads (20%) | catalogued as rs1362800658; called by muse, varscan2
- MTF2 | c.1188del p.G397Efs*6 | Frame Shift Del (DEL) | VAF 28/158 reads (18%) | catalogued as rs759847587; called by mutect2, varscan2
- MTSS2 | c.1634C>T p.A545V | Missense Mutation (SNP) | VAF 104/616 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.047); catalogued as rs775786354, COSV55380392; called by muse, mutect2, varscan2
- MUC1 | c.3536C>T p.A1179V (on ENST00000611571 / NM_001371720.1; = p.A190V on NM_002456.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 68/348 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.411); catalogued as rs200788986, COSV58116984; called by muse, mutect2, varscan2
- MUC5B | c.9772C>G p.P3258A | Missense Mutation (SNP) | VAF 112/592 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0.044); catalogued as rs779916196; called by muse, mutect2, varscan2
- MVK | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 79/396 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs778337320, COSV57332232; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH14 | c.1615G>A p.D539N | Missense Mutation (SNP) | VAF 30/266 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs762779652; called by muse, mutect2, varscan2
- MYH3 | c.4138G>A p.A1380T | Missense Mutation (SNP) | VAF 17/386 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.595); catalogued as COSV56862921; called by muse, mutect2
- MYH3 | c.3997G>A p.A1333T | Missense Mutation (SNP) | VAF 51/370 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.49); catalogued as rs200734527, COSV56863991, COSV56865662; called by muse, mutect2, varscan2
- MYH6 | c.3476C>T p.T1159M | Missense Mutation (SNP) | VAF 70/566 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs780305056; ClinVar: uncertain significance; called by muse, varscan2
- MYLPF | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 44/301 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1237788851, COSV100363062; called by muse, mutect2, varscan2
- MYO10 | c.403G>A p.A135T | Missense Mutation (SNP) | VAF 34/486 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1287344494; called by muse, mutect2
- MYO18B | c.6745G>A p.A2249T | Missense Mutation (SNP) | VAF 62/357 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100125305, COSV59133074; called by muse, varscan2
- MYO9A | c.4483A>G p.T1495A | Missense Mutation (SNP) | VAF 81/433 reads (19%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.001); catalogued as rs769974077; called by muse, mutect2, varscan2
- NALCN | c.1121del p.P374Qfs*7 | Frame Shift Del (DEL) | VAF 33/296 reads (11%) | catalogued as COSV99214138; called by mutect2, pindel, varscan2
- NAPEPLD | c.842del p.F281Sfs*14 | Frame Shift Del (DEL) | VAF 71/384 reads (18%) | catalogued as rs746683932, COSV100439928; called by mutect2, varscan2
- NBEAL2 | c.796G>A p.A266T | Missense Mutation (SNP) | VAF 105/513 reads (20%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs367790977; called by muse, mutect2, varscan2
- NCOA2 | c.1472G>A p.R491H | Missense Mutation (SNP) | VAF 82/559 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs757931284, COSV71763730; called by muse, varscan2
- NCOR2 | c.1252G>A p.D418N | Missense Mutation (SNP) | VAF 57/358 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62299516; called by muse, mutect2, varscan2
- NEB | c.3209C>T p.A1070V | Missense Mutation (SNP) | VAF 58/276 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs371710158, COSV51372626; called by muse, mutect2, varscan2
- NEFH | c.1037G>A p.R346H | Missense Mutation (SNP) | VAF 57/328 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs1401155915; called by muse, mutect2, varscan2
- NEGR1 | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 48/290 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1248852117, COSV100165398, COSV60868612, COSV60871717; called by muse, mutect2, varscan2
- NEURL1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 76/462 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs535287090, COSV99056679; called by muse, mutect2, varscan2
- NGEF | c.1388G>A p.R463H | Missense Mutation (SNP) | VAF 41/334 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1293653144, COSV50916359, COSV50949427; called by muse, mutect2, varscan2
- NID2 | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 49/507 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as rs898511207; called by muse, varscan2
- NIPA2 | c.101del p.G34Afs*11 | Frame Shift Del (DEL) | VAF 54/298 reads (18%) | catalogued as rs111948120; called by mutect2, pindel, varscan2
- NKX1-1 | c.1319C>T p.A440V | Missense Mutation (SNP) | VAF 62/376 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1480235048; called by muse, mutect2, varscan2
- NKX1-1 | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 91/590 reads (15%) | SIFT tolerated, low confidence (0.17); catalogued as rs1267747077; called by muse, mutect2, varscan2
- NKX2-2 | c.649G>A p.A217T | Missense Mutation (SNP) | VAF 82/524 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs763629654, COSV101010611; called by muse, mutect2, varscan2
- NKX6-1 | c.1051G>A p.G351S | Missense Mutation (SNP) | VAF 79/391 reads (20%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV55683931; called by muse, mutect2, varscan2
- NLRP12 | c.1231T>G p.C411G | Missense Mutation (SNP) | VAF 62/469 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60748462; called by muse, mutect2, varscan2
- NOD1 | c.416G>A p.R139H | Missense Mutation (SNP) | VAF 58/346 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.802); catalogued as rs549088103; called by muse, mutect2, varscan2
- NOTCH3 | c.1036+1G>A p.X346_splice | Splice Site (SNP) | VAF 58/224 reads (26%) | catalogued as COSV54627422; called by muse, mutect2, varscan2
- NOX3 | c.1033dup p.Q345Pfs*83 | Frame Shift Ins (INS) | VAF 67/479 reads (14%) | catalogued as rs1265462829; called by mutect2, pindel, varscan2
- NPC1 | c.916G>A p.D306N | Missense Mutation (SNP) | VAF 42/296 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.023); catalogued as rs747243586; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NR1H2 | c.788G>A p.R263H | Missense Mutation (SNP) | VAF 62/364 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.086); catalogued as rs763608025, COSV53802626; called by muse, varscan2
- NR2F2 | c.910G>A p.A304T | Missense Mutation (SNP) | VAF 55/325 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.021); catalogued as rs764508071; called by muse, mutect2, varscan2
- NRK | c.4120C>T p.R1374* | Nonsense Mutation (SNP) | VAF 61/190 reads (32%) | catalogued as rs768058273, COSV54600228; called by muse, mutect2, varscan2
- NUP210 | c.3301G>A p.E1101K | Missense Mutation (SNP) | VAF 60/270 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.26); catalogued as rs200679883, COSV54402313; called by muse, mutect2, varscan2
- NUP210 | c.2912C>T p.A971V | Missense Mutation (SNP) | VAF 47/319 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.153); catalogued as COSV54405236; called by muse, mutect2, varscan2
- NUP42 | c.212dup p.S72Qfs*13 | Frame Shift Ins (INS) | VAF 58/362 reads (16%) | catalogued as rs758695627; called by mutect2, varscan2
- NXNL1 | c.205C>T p.R69W | Missense Mutation (SNP) | VAF 68/355 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs372287276, COSV100112018; called by muse, mutect2, varscan2
- OAZ1 | c.662_663dup p.S223Lfs*72 | Frame Shift Ins (INS) | VAF 56/300 reads (19%) | catalogued as rs1381276805; called by mutect2, varscan2
- OBP2A | c.362del p.G121Afs*87 | Frame Shift Del (DEL) | VAF 41/255 reads (16%) | catalogued as rs778649918; called by mutect2, pindel, varscan2
- OPTN | c.76del p.H26Tfs*19 | Frame Shift Del (DEL) | VAF 75/390 reads (19%) | catalogued as rs753966040; called by mutect2, pindel, varscan2
- OR13C2 | c.569C>G p.A190G | Missense Mutation (SNP) | VAF 66/307 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.05); catalogued as rs267602071; called by muse, mutect2, varscan2
- OR2AT4 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 69/394 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as rs369166223, COSV59406783; called by muse, mutect2, varscan2
- OR2G6 | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 64/359 reads (18%) | SIFT tolerated (0.65); PolyPhen benign (0.015); catalogued as rs375204402, COSV58573740; called by muse, mutect2, varscan2
- OR4N2 | c.28A>G p.R10G | Missense Mutation (SNP) | VAF 30/252 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as rs1215232372; called by muse, mutect2, varscan2
- OR4S1 | c.692G>A p.R231Q | Missense Mutation (SNP) | VAF 72/385 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.133); catalogued as rs778563869; called by muse, varscan2
- OR51E1 | c.466del p.A156Lfs*3 | Frame Shift Del (DEL) | VAF 60/387 reads (16%) | catalogued as rs1564877761; called by mutect2, pindel, varscan2
- OR56A3 | c.448A>G p.M150V | Missense Mutation (SNP) | VAF 66/385 reads (17%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs376082899; called by muse, mutect2, varscan2
- OR5AC2 | c.730G>A p.G244S | Missense Mutation (SNP) | VAF 56/332 reads (17%) | SIFT tolerated (0.76); PolyPhen benign (0.025); catalogued as rs193920759, COSV62279352; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR5D16 | c.431C>T p.A144V | Missense Mutation (SNP) | VAF 18/446 reads (4%) | SIFT tolerated (0.36); PolyPhen benign (0.031); catalogued as COSV65722731; called by muse, mutect2
- OR5M3 | c.265dup p.T89Nfs*31 | Frame Shift Ins (INS) | VAF 44/309 reads (14%) | catalogued as rs780048280; called by mutect2, varscan2
- OR6P1 | c.96del p.F32Lfs*6 | Frame Shift Del (DEL) | VAF 39/287 reads (14%) | catalogued as rs201077183; called by mutect2, varscan2
- OR8B2 | c.940T>C p.*314Qext*? | Nonstop Mutation (SNP) | VAF 18/155 reads (12%) | catalogued as rs1314103251; called by muse, mutect2, varscan2
- ORAI2 | c.539G>A p.R180H | Missense Mutation (SNP) | VAF 116/658 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs373392032; called by muse, mutect2, varscan2
- OS9 | c.1790G>A p.R597H | Missense Mutation (SNP) | VAF 66/355 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as rs766581613, COSV57731387; called by muse, mutect2, varscan2
- OSCAR | c.577G>A p.A193T | Missense Mutation (SNP) | VAF 124/648 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.038); catalogued as rs1338110437; called by muse, varscan2
- OSGIN2 | c.1433C>T p.A478V | Missense Mutation (SNP) | VAF 66/395 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs201554027, COSV52412274; called by muse, mutect2, varscan2
- OTUD6A | c.671C>T p.A224V | Missense Mutation (SNP) | VAF 103/279 reads (37%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); catalogued as COSV100611111; called by muse, mutect2, varscan2
- OXER1 | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 104/467 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); catalogued as rs780052387, COSV99685605; called by muse, mutect2, varscan2
- PA2G4 | c.1115del p.K372Rfs*16 | Frame Shift Del (DEL) | VAF 40/247 reads (16%) | catalogued as rs746871475; called by mutect2, varscan2
- PABPC1L | c.1066C>T p.R356C | Missense Mutation (SNP) | VAF 91/558 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs199499305; called by muse, mutect2, varscan2
- PANK4 | c.1000C>T p.R334C | Missense Mutation (SNP) | VAF 69/489 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); catalogued as rs768050088; called by muse, varscan2
- PAPOLB | c.58C>T p.R20C | Missense Mutation (SNP) | VAF 75/469 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.873); catalogued as rs776058217; called by muse, mutect2, varscan2
- PAPPA | c.829G>A p.A277T | Missense Mutation (SNP) | VAF 81/455 reads (18%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs374755308, COSV60277259; called by muse, mutect2, varscan2
- PAX3 | c.232G>A p.V78M | Missense Mutation (SNP) | VAF 74/438 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM950899, COSV99286399; called by muse, mutect2, varscan2
- PBRM1 | c.1376C>T p.A459V | Missense Mutation (SNP) | VAF 58/343 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56305288; called by muse, mutect2, varscan2
- PCDH10 | c.1781C>T p.A594V | Missense Mutation (SNP) | VAF 98/496 reads (20%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.997); catalogued as rs1400031919, COSV52090235; called by muse, mutect2, varscan2
- PCDH15 | c.1040T>C p.L347P | Missense Mutation (SNP) | VAF 26/250 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57299220, COSV57350026; called by muse, mutect2
- PCDH8 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 32/602 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.899); catalogued as rs1263350489, COSV58812442; called by muse, mutect2
- PCDHB2 | c.1597G>A p.V533M | Missense Mutation (SNP) | VAF 124/686 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.957); catalogued as rs571621697; called by muse, varscan2
- PCDHB7 | c.1898G>A p.R633H | Missense Mutation (SNP) | VAF 124/1496 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.479); catalogued as rs375792075; called by muse, mutect2
- PCDHB8 | c.557G>A p.R186H | Missense Mutation (SNP) | VAF 62/708 reads (9%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.021); catalogued as rs781828540, COSV50809206; called by muse, mutect2
- PCDHGC5 | c.2267C>T p.T756M | Missense Mutation (SNP) | VAF 100/433 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.964); catalogued as COSV52768378; called by muse, mutect2, varscan2
- PCED1A | c.1269dup p.P424Afs*57 | Frame Shift Ins (INS) | VAF 54/364 reads (15%) | catalogued as rs772305388; called by mutect2, varscan2
- PCIF1 | c.2066G>A p.R689Q | Missense Mutation (SNP) | VAF 91/445 reads (20%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs750766782; called by muse, mutect2, varscan2
- PCK2 | c.1342G>A p.A448T | Missense Mutation (SNP) | VAF 39/451 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs551184706, COSV53748018; called by muse, mutect2
- PDIA3 | c.1504del p.Q502Rfs*46 | Frame Shift Del (DEL) | VAF 43/287 reads (15%) | catalogued as COSV55857502; called by mutect2, pindel, varscan2
- PDZD7 | c.2182del p.L728Sfs*25 | Frame Shift Del (DEL) | VAF 34/215 reads (16%) | catalogued as rs1162586274; called by mutect2, pindel, varscan2
- PDZRN3 | c.2612C>T p.A871V | Missense Mutation (SNP) | VAF 77/532 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs1472294841, COSV55212681; called by muse, mutect2, varscan2
- PDZRN3 | c.1783G>A p.A595T | Missense Mutation (SNP) | VAF 79/472 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1224723802, COSV99732903; called by muse, mutect2, varscan2
- PDZRN4 | c.395del p.G132Afs*96 | Frame Shift Del (DEL) | VAF 33/239 reads (14%) | catalogued as rs1203008747; called by mutect2, pindel, varscan2
- PERM1 | c.815C>T p.P272L | Missense Mutation (SNP) | VAF 112/533 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.028); catalogued as rs947727148; called by muse, mutect2, varscan2
- PF4V1 | c.41G>A p.R14H | Missense Mutation (SNP) | VAF 59/322 reads (18%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.162); catalogued as COSV56953660; called by muse, varscan2
- PFN4 | c.381del p.G128Efs*38 | Frame Shift Del (DEL) | VAF 37/268 reads (14%) | catalogued as COSV57531609; called by mutect2, pindel, varscan2
- PHACTR2 | c.298G>A p.G100R | Missense Mutation (SNP) | VAF 57/294 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1225668209; called by muse, mutect2, varscan2
- PHACTR4 | c.214C>T p.R72* (on ENST00000373839 / NM_001350159.2; = p.R82* on NM_023923.4) | Nonsense Mutation (SNP) | VAF 24/265 reads (9%) | catalogued as rs1468459755, COSV65783253; called by muse, mutect2
- PHF2 | c.1178del p.P393Lfs*3 | Frame Shift Del (DEL) | VAF 40/250 reads (16%) | catalogued as COSV63683843; called by mutect2, pindel, varscan2
- PHF3 | c.3408del p.V1137* | Frame Shift Del (DEL) | VAF 65/275 reads (24%) | catalogued as rs1163689977; called by mutect2, pindel, varscan2
- PIEZO1 | c.7150G>A p.G2384S | Missense Mutation (SNP) | VAF 66/374 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as rs779772252; called by muse, varscan2
- PIEZO1 | c.7136_7138del p.E2379del | In Frame Del (DEL) | VAF 54/340 reads (16%) | catalogued as rs1370020259; called by pindel, varscan2
- PIP5K1C | c.1097C>T p.A366V | Missense Mutation (SNP) | VAF 76/477 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as rs375595357; called by muse, mutect2, varscan2
- PKD1L2 | c.1183G>A p.A395T | Missense Mutation (SNP) | VAF 41/285 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0.12); catalogued as rs745626947; called by muse, varscan2
- PKD2L2 | c.1245dup p.I416Yfs*19 | Frame Shift Ins (INS) | VAF 36/265 reads (14%) | catalogued as rs761604235; called by pindel, varscan2
- PKDREJ | c.610G>A p.V204I | Missense Mutation (SNP) | VAF 67/471 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1304020096, COSV53551148; called by muse, mutect2, varscan2
- PKN2 | c.232dup p.S78Kfs*14 | Frame Shift Ins (INS) | VAF 46/253 reads (18%) | catalogued as rs1335792632; called by mutect2, varscan2
- PLA2G2A | c.200A>G p.H67R | Missense Mutation (SNP) | VAF 42/232 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs780409037; called by muse, mutect2, varscan2
- PLCH1 | c.2455C>T p.R819* (on ENST00000340059 / NM_001130960.2; = p.R831* on NM_014996.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 67/353 reads (19%) | catalogued as rs773951695, COSV58184975; called by muse, mutect2, varscan2
- PLD2 | c.2678G>A p.R893Q | Missense Mutation (SNP) | VAF 94/475 reads (20%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs759703141; called by muse, mutect2, varscan2
- PLEC | c.6421C>T p.R2141W (on ENST00000322810 / NM_201380.4; = p.R2031W on NM_000445.5) | Missense Mutation (SNP) | VAF 111/725 reads (15%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as rs369813798; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLK2 | c.1709C>T p.T570M | Missense Mutation (SNP) | VAF 54/312 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.97); catalogued as rs149934516; called by muse, varscan2
- PLPBP | c.734C>T p.T245M | Missense Mutation (SNP) | VAF 25/234 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.38); catalogued as rs144784344; called by muse, mutect2, varscan2
- PLXNA4 | c.296G>A p.R99H | Missense Mutation (SNP) | VAF 72/437 reads (16%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.631); catalogued as rs374157944, COSV100326832; called by muse, varscan2
- PMS2 | c.2374G>A p.D792N | Missense Mutation (SNP) | VAF 50/324 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as rs587781265; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PNPLA7 | c.3522del p.I1175Sfs*148 | Frame Shift Del (DEL) | VAF 91/483 reads (19%) | catalogued as rs761459630; called by mutect2, pindel, varscan2
- PNRC1 | c.301_303del p.K101del | In Frame Del (DEL) | VAF 96/558 reads (17%) | catalogued as rs746966684; called by pindel, varscan2
- POLM | c.337C>T p.Q113* | Nonsense Mutation (SNP) | VAF 55/345 reads (16%) | catalogued as rs767951463, COSV54242612; called by muse, mutect2, varscan2
- POLR1F | c.194A>G p.N65S | Missense Mutation (SNP) | VAF 85/436 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as rs368519673; called by muse, mutect2, varscan2
- POTEA | c.1594C>T p.R532W (on ENST00000519951 / NM_001005365.2; = p.R486W on NM_001002920.1) | Missense Mutation (SNP) | VAF 24/220 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs943600747; called by muse, varscan2
- POU3F3 | c.901G>T p.A301S | Missense Mutation (SNP) | VAF 110/656 reads (17%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0.013); catalogued as COSV63721324; called by muse, varscan2
- PPARD | c.1240G>A p.A414T | Missense Mutation (SNP) | VAF 70/437 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as rs867021538, COSV100283209; called by muse, mutect2, varscan2
- PPP1R10 | c.2255G>A p.R752H | Missense Mutation (SNP) | VAF 84/578 reads (15%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.057); catalogued as rs747071643, COSV64738754; called by muse, varscan2
- PPP1R13B | c.1531del p.Q511Sfs*39 | Frame Shift Del (DEL) | VAF 97/530 reads (18%) | catalogued as rs758922105; called by mutect2, pindel, varscan2
- PPP1R13L | c.2044G>A p.A682T | Missense Mutation (SNP) | VAF 70/397 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV62908917; called by muse, mutect2, varscan2
- PPP1R14C | c.481C>T p.Q161* | Nonsense Mutation (SNP) | VAF 58/306 reads (19%) | catalogued as COSV63173947; called by muse, varscan2
- PPP1R3G | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 99/508 reads (19%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.015); catalogued as rs1203775197; called by muse, mutect2, varscan2
- PPP1R42 | c.461G>A p.S154N | Missense Mutation (SNP) | VAF 9/217 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.21); catalogued as COSV61207520; called by muse, mutect2
- PPP4R3A | c.1132C>T p.R378* | Nonsense Mutation (SNP) | VAF 36/197 reads (18%) | catalogued as COSV61504736; called by muse, mutect2, varscan2
- PRDM13 | c.1778G>A p.R593Q | Missense Mutation (SNP) | VAF 113/542 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65030141; called by muse, mutect2, varscan2
- PRKAA2 | c.1331del p.N444Ifs*3 | Frame Shift Del (DEL) | VAF 41/260 reads (16%) | catalogued as COSV64802054; called by mutect2, pindel, varscan2
- PROM2 | c.701G>A p.G234E | Missense Mutation (SNP) | VAF 70/398 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs766515604; called by muse, varscan2
- PRR36 | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 52/343 reads (15%) | SIFT deleterious, low confidence (0); catalogued as rs550257479; called by muse, mutect2, varscan2
- PRRG1 | c.401dup p.P135Tfs*3 | Frame Shift Ins (INS) | VAF 25/104 reads (24%) | catalogued as rs781858060, COSV66158042; called by mutect2, varscan2
- PRRX2 | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 58/420 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.75); catalogued as rs902523494; called by muse, mutect2, varscan2
- PRSS53 | c.81C>A p.A27= | Splice Region (SNP) | VAF 80/415 reads (19%) | catalogued as COSV54924882; called by muse, mutect2
- PSD | c.593del p.G198Afs*19 | Frame Shift Del (DEL) | VAF 105/570 reads (18%) | catalogued as COSV99194092; called by mutect2, pindel, varscan2
- PTGS2 | c.169C>T p.P57S | Missense Mutation (SNP) | VAF 37/217 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.585); catalogued as rs373745396; called by muse, mutect2, varscan2
- PTK2B | c.2327G>A p.R776H | Missense Mutation (SNP) | VAF 43/274 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs544742483, COSV57753286; called by muse, mutect2, varscan2
- PTPN21 | c.692A>G p.D231G | Missense Mutation (SNP) | VAF 36/330 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.559); catalogued as rs1243349755; called by muse, mutect2, varscan2
- PTPN3 | c.2251C>T p.R751W | Missense Mutation (SNP) | VAF 34/211 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52705254; called by muse, mutect2, varscan2
- PTPRA | c.667G>A p.V223M | Missense Mutation (SNP) | VAF 62/424 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs373627310; called by muse, varscan2
- PTPRC | c.1253C>G p.S418* | Nonsense Mutation (SNP) | VAF 38/293 reads (13%) | catalogued as COSV61407517, COSV61412223; called by muse, mutect2, varscan2
- PTPRE | c.1277T>C p.L426P | Missense Mutation (SNP) | VAF 55/334 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs895352370; called by muse, mutect2, varscan2
- PTPRS | c.1430A>C p.K477T | Missense Mutation (SNP) | VAF 92/502 reads (18%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.948); catalogued as rs1191866085; called by mutect2, varscan2
- PWWP2B | c.257del p.P86Lfs*100 | Frame Shift Del (DEL) | VAF 64/342 reads (19%) | catalogued as rs1234606471; called by mutect2, varscan2
- PXDN | c.3592C>T p.R1198W | Missense Mutation (SNP) | VAF 36/267 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs570640127, COSV53237614, COSV99412394; called by muse, mutect2, varscan2
- PXDN | c.2276C>T p.S759L | Missense Mutation (SNP) | VAF 101/497 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.909); catalogued as rs200731840, COSV53229398; called by muse, mutect2, varscan2
- RAB19 | c.509_511del p.E170del | In Frame Del (DEL) | VAF 64/362 reads (18%) | catalogued as rs751346314; called by pindel, varscan2
- RAB42 | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 47/544 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs765050696, COSV100866068; called by muse, mutect2
- RAI2 | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 28/330 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771404978, COSV100518135; called by muse, mutect2
- RALB | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 71/340 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.869); catalogued as rs745779129; called by muse, mutect2, varscan2
- RALGAPA2 | c.3170C>T p.T1057M | Missense Mutation (SNP) | VAF 46/203 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as rs373754711; called by muse, mutect2, varscan2
- RASL10B | c.596G>A p.R199H | Missense Mutation (SNP) | VAF 64/396 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.233); catalogued as rs1397660851; called by muse, mutect2, varscan2
- RBBP8NL | c.432dup p.S145Lfs*26 | Frame Shift Ins (INS) | VAF 106/548 reads (19%) | catalogued as rs749848235; called by mutect2, varscan2
- RBPJL | c.686G>A p.R229H | Missense Mutation (SNP) | VAF 86/423 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs907710511, COSV59213995; called by muse, mutect2, varscan2
- RFPL1 | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 76/504 reads (15%) | SIFT tolerated (0.53); PolyPhen benign (0.009); catalogued as rs371158882, COSV62978332; called by muse, varscan2
- RGS11 | c.766G>A p.G256S (on ENST00000397770 / NM_183337.3; = p.G235S on NM_003834.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/343 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs138806270; called by muse, mutect2, varscan2
- RGS12 | c.3925G>A p.A1309T | Missense Mutation (SNP) | VAF 36/510 reads (7%) | SIFT tolerated (0.64); PolyPhen benign (0.026); catalogued as rs144400688; called by muse, mutect2
- RGS19 | c.233C>T p.T78M | Missense Mutation (SNP) | VAF 62/340 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs1202226228, COSV58657341; called by muse, mutect2, varscan2
- RHOXF2 | c.330C>A p.S110R | Missense Mutation (SNP) | VAF 128/593 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.023); catalogued as COSV65048046; called by muse, mutect2, varscan2
- RIBC1 | c.623C>T p.A208V | Missense Mutation (SNP) | VAF 74/239 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs782772772, COSV51447415; called by muse, mutect2, varscan2
- RNF152 | c.148C>T p.R50W | Missense Mutation (SNP) | VAF 26/496 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs768728944, COSV57184144; called by muse, mutect2
- RNF220 | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 86/466 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs931264312, COSV62409077, COSV62410430; called by muse, mutect2, varscan2
- RNF227 | c.19G>A p.V7I | Missense Mutation (SNP) | VAF 49/236 reads (21%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.012); catalogued as rs1375670652; called by muse, mutect2, varscan2
- RNF25 | c.749del p.G250Efs*29 | Frame Shift Del (DEL) | VAF 55/360 reads (15%) | catalogued as rs746813141; called by mutect2, varscan2
- RNH1 | c.1237G>A p.A413T | Missense Mutation (SNP) | VAF 93/562 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs370277229; called by muse, mutect2, varscan2
- ROBO4 | c.1459G>A p.V487M | Missense Mutation (SNP) | VAF 95/481 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.138); catalogued as rs772019553, COSV60625386; called by muse, mutect2, varscan2
- RPL34 | c.*5del | Frame Shift Del (DEL) | VAF 23/151 reads (15%) | catalogued as rs761738263; called by mutect2, varscan2
- RPS6KA2 | c.665C>T p.T222M | Missense Mutation (SNP) | VAF 81/406 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs751151339, COSV55820483; called by muse, mutect2, varscan2
- RPTOR | c.1604C>T p.T535M | Missense Mutation (SNP) | VAF 86/438 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as rs866939416, COSV60817758; called by muse, mutect2, varscan2
- RPTOR | c.2362C>T p.R788C | Missense Mutation (SNP) | VAF 67/334 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.795); catalogued as rs781190662, COSV60811595; called by muse, mutect2, varscan2
- RREB1 | c.2156G>A p.R719H | Missense Mutation (SNP) | VAF 84/507 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1285855648, COSV58555685; called by muse, mutect2, varscan2
- RRM1 | c.1496G>A p.R499H | Missense Mutation (SNP) | VAF 59/319 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV56162867; called by muse, mutect2, varscan2
- RRP36 | c.595C>T p.R199C | Missense Mutation (SNP) | VAF 67/340 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as rs1176901871; called by muse, mutect2, varscan2
- RTN2 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 78/482 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.04); catalogued as COSV99838857; called by muse, mutect2, varscan2
- RUNX1T1 | c.66dup p.G23Rfs*4 | Frame Shift Ins (INS) | VAF 36/286 reads (13%) | catalogued as rs1419748338; called by mutect2, pindel, varscan2
- RXFP2 | c.1549A>G p.T517A | Missense Mutation (SNP) | VAF 62/395 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs779844058; called by muse, mutect2, varscan2
- RYR3 | c.313T>C p.Y105H | Missense Mutation (SNP) | VAF 59/314 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747793013; called by muse, mutect2, varscan2
- SAMD11 | c.1987_1989del p.E663del | In Frame Del (DEL) | VAF 56/447 reads (13%) | catalogued as rs1167117919; called by mutect2, pindel, varscan2
- SARAF | c.538G>A p.V180M | Missense Mutation (SNP) | VAF 56/364 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); catalogued as rs767021861; called by mutect2, varscan2
- SASS6 | c.170del p.L57Yfs*14 | Frame Shift Del (DEL) | VAF 44/206 reads (21%) | catalogued as rs763290832; called by mutect2, varscan2
- SCN2A | c.1723G>A p.A575T | Missense Mutation (SNP) | VAF 67/298 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs766254071; called by muse, mutect2, varscan2
- SCRIB | c.4237G>A p.E1413K | Missense Mutation (SNP) | VAF 102/691 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs782135048; called by muse, mutect2, varscan2
- SCRT2 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 42/211 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as COSV55728905; called by muse, mutect2, varscan2
- SDR42E2 | c.665G>A p.R222H | Missense Mutation (SNP) | VAF 50/329 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771242010; called by muse, mutect2, varscan2
- SEMA4C | c.2272C>G p.P758A | Missense Mutation (SNP) | VAF 85/501 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.095); catalogued as rs908604554, COSV59691051; called by muse, mutect2, varscan2
- SEPTIN1 | c.859C>T p.R287W (on ENST00000321367; = p.R240W on NM_052838.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 78/399 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as rs765469218, COSV58442538; called by muse, mutect2, varscan2
- SERPINA5 | c.274C>A p.L92M | Missense Mutation (SNP) | VAF 78/420 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV61575252; called by muse, mutect2, varscan2
- SERPINA9 | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 46/328 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV54077311; called by muse, mutect2
- SESN2 | c.1411G>A p.A471T | Missense Mutation (SNP) | VAF 28/308 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.541); catalogued as rs756166147; called by muse, mutect2
- SETBP1 | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 74/438 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs140717709; called by muse, mutect2, varscan2
- SETX | c.6695G>A p.R2232H | Missense Mutation (SNP) | VAF 64/345 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56378306, COSV99808481; called by muse, mutect2, varscan2
- SFSWAP | c.2476C>T p.P826S | Missense Mutation (SNP) | VAF 58/382 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.994); catalogued as rs1257900602; called by muse, varscan2
- SGCD | c.29G>A p.R10Q (on ENST00000435422 / NM_001128209.2; = p.R11Q on NM_000337.5) | Missense Mutation (SNP) | VAF 58/235 reads (25%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.968); catalogued as rs752548592, COSV61903106; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SGMS1 | c.905G>A p.R302Q | Missense Mutation (SNP) | VAF 31/238 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.74); catalogued as rs147939399; called by muse, mutect2, varscan2
- SHANK2 | c.2261C>T p.S754L | Missense Mutation (SNP) | VAF 86/420 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.199); catalogued as rs1555158815; called by muse, mutect2, varscan2
- SHARPIN | c.722C>T p.A241V | Missense Mutation (SNP) | VAF 67/481 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.054); catalogued as rs1380542340; called by muse, mutect2, varscan2
- SHCBP1L | c.1017del p.K339Nfs*5 | Frame Shift Del (DEL) | VAF 43/271 reads (16%) | catalogued as rs756742767; called by mutect2, pindel, varscan2
- SHE | c.1165C>T p.P389S | Missense Mutation (SNP) | VAF 60/321 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.186); catalogued as COSV59073480; called by muse, mutect2, varscan2
- SHF | c.754G>A p.A252T | Missense Mutation (SNP) | VAF 74/444 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as rs372173164; called by muse, mutect2, varscan2
- SHPRH | c.1993G>A p.E665K | Missense Mutation (SNP) | VAF 30/450 reads (7%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.998); catalogued as rs758183894, COSV51606495; called by muse, mutect2
- SIX1 | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 72/388 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV55959768; called by muse, varscan2
- SLC10A4 | c.1061C>T p.P354L | Missense Mutation (SNP) | VAF 66/419 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772139890; called by muse, mutect2, varscan2
- SLC12A8 | c.263C>T p.T88M | Missense Mutation (SNP) | VAF 92/479 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs375202810; called by muse, mutect2, varscan2
- SLC15A4 | c.1492G>A p.V498I | Missense Mutation (SNP) | VAF 38/337 reads (11%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as rs766478288; called by muse, mutect2, varscan2
- SLC17A8 | c.1386G>A p.M462I | Missense Mutation (SNP) | VAF 38/295 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.241); catalogued as COSV60125846; called by muse, mutect2, varscan2
- SLC24A1 | c.847C>T p.P283S | Missense Mutation (SNP) | VAF 88/464 reads (19%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as rs956792845, COSV99978191; called by muse, mutect2, varscan2
- SLC25A38 | c.523C>T p.R175W | Missense Mutation (SNP) | VAF 54/383 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs368788683, COSV56194082; called by muse, mutect2, varscan2
- SLC30A3 | c.946C>T p.R316W | Missense Mutation (SNP) | VAF 71/418 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as rs1227936370; called by muse, mutect2, varscan2
- SLC35F3 | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 70/462 reads (15%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.883); catalogued as rs747640163, COSV64031737; called by muse, mutect2
- SLC39A5 | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 99/553 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs574176268, COSV57191955; called by muse, mutect2, varscan2
- SLC45A4 | c.1358G>A p.R453H (on ENST00000517878 / NM_001286646.2; = p.R402H on NM_001080431.2) | Missense Mutation (SNP) | VAF 121/661 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as rs748393317, COSV50132972; called by muse, mutect2, varscan2
- SLC4A3 | c.470_471del p.H157Lfs*14 | Frame Shift Del (DEL) | VAF 37/392 reads (9%) | catalogued as rs1272891190; called by mutect2, pindel
- SLC4A9 | c.2545del p.V849Wfs*13 (on ENST00000507527 / NM_001258428.2; = p.V825Wfs*13 on NM_031467.3) | Frame Shift Del (DEL) | VAF 52/321 reads (16%) | catalogued as COSV99138498; called by mutect2, pindel, varscan2
- SLC6A5 | c.2041T>C p.W681R | Missense Mutation (SNP) | VAF 55/303 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1250911193; called by muse, mutect2, varscan2
- SLC9C2 | c.1108C>T p.R370* | Nonsense Mutation (SNP) | VAF 44/246 reads (18%) | catalogued as rs559322659, COSV62947011; called by muse, varscan2
- SLCO2B1 | c.1376C>T p.P459L | Missense Mutation (SNP) | VAF 90/379 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755350290; called by muse, mutect2, varscan2
- SLITRK5 | c.1331G>A p.R444H | Missense Mutation (SNP) | VAF 69/393 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV61524481; called by muse, mutect2, varscan2
- SMAD6 | c.1253A>G p.D418G | Missense Mutation (SNP) | VAF 70/471 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as COSV56593877; called by muse, mutect2, varscan2
- SMC2 | c.2251del p.T751Pfs*9 | Frame Shift Del (DEL) | VAF 30/198 reads (15%) | catalogued as rs1257129093; called by mutect2, pindel, varscan2
- SORBS1 | c.3139C>T p.R1047* | Nonsense Mutation (SNP) | VAF 77/459 reads (17%) | catalogued as rs555941537, COSV53364551; called by muse, mutect2, varscan2
- SOST | c.362G>A p.R121H | Missense Mutation (SNP) | VAF 102/513 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.569); catalogued as rs1420343521; called by muse, mutect2, varscan2
- SPAG1 | c.1819G>A p.G607R | Missense Mutation (SNP) | VAF 62/345 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.028); catalogued as rs1269175079; called by muse, mutect2, varscan2
- SPC24 | c.494A>G p.H165R | Missense Mutation (SNP) | VAF 52/274 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.745); catalogued as rs746090767; called by muse, mutect2, varscan2
- SPECC1 | c.908del p.N303Tfs*63 | Frame Shift Del (DEL) | VAF 46/292 reads (16%) | catalogued as COSV54965656; called by mutect2, varscan2
- SPICE1 | c.961G>A p.A321T | Missense Mutation (SNP) | VAF 72/409 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs780026428; called by muse, mutect2, varscan2
- SPIRE2 | c.1633C>T p.R545C | Missense Mutation (SNP) | VAF 62/458 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1302510580; called by muse, mutect2, varscan2
- SPOCK1 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 53/304 reads (17%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.015); catalogued as COSV56467409; called by muse, mutect2, varscan2
- SPOCK2 | c.290G>A p.R97H | Missense Mutation (SNP) | VAF 38/294 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as rs186824562; called by muse, varscan2
- SPON1 | c.1830C>T p.C610= | Splice Region (SNP) | VAF 55/286 reads (19%) | catalogued as COSV100116315; called by muse, mutect2, varscan2
- SRCAP | c.5633del p.P1878Hfs*89 | Frame Shift Del (DEL) | VAF 46/222 reads (21%) | catalogued as rs748467821; called by mutect2, varscan2
- SREBF1 | c.1757G>A p.R586H | Missense Mutation (SNP) | VAF 47/414 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs147642834, COSV55416399; called by muse, mutect2, varscan2
- SREBF2 | c.2293del p.L765Wfs*13 | Frame Shift Del (DEL) | VAF 59/375 reads (16%) | catalogued as COSV63331442; called by mutect2, pindel, varscan2
- SS18 | c.350C>T p.P117L | Missense Mutation (SNP) | VAF 45/330 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.736); catalogued as rs149732063; called by muse, mutect2, varscan2
- SSC5D | c.580del p.R194Afs*41 | Frame Shift Del (DEL) | VAF 45/188 reads (24%) | catalogued as rs1289848908, COSV99219985; called by mutect2, pindel, varscan2
- ST6GALNAC1 | c.1534G>A p.A512T | Missense Mutation (SNP) | VAF 43/237 reads (18%) | PolyPhen benign (0.027); catalogued as rs761992560, COSV50079587; called by muse, mutect2, varscan2
- ST6GALNAC4 | c.661G>A p.A221T | Missense Mutation (SNP) | VAF 50/297 reads (17%) | PolyPhen probably damaging (0.999); catalogued as rs1044157603; called by muse, mutect2, varscan2
- ST8SIA6 | c.753del p.A252Pfs*53 | Frame Shift Del (DEL) | VAF 57/240 reads (24%) | catalogued as rs758746672, COSV66468613; called by mutect2, varscan2
- STAB1 | c.6902G>A p.R2301H | Missense Mutation (SNP) | VAF 63/330 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs184802643; called by muse, mutect2
- STK17A | c.1231G>T p.E411* | Nonsense Mutation (SNP) | VAF 38/207 reads (18%) | catalogued as rs1260082945; called by muse, mutect2, varscan2
- STK40 | c.1219G>A p.A407T | Missense Mutation (SNP) | VAF 66/379 reads (17%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.01); catalogued as rs564284695; called by muse, varscan2
- STRN4 | c.1985G>A p.R662H | Missense Mutation (SNP) | VAF 46/303 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs560915215, COSV54416450; called by muse, mutect2, varscan2
- SUGCT | c.1206del p.L403Cfs*10 (on ENST00000335693 / NM_001193313.2; = p.L429Cfs*10 on NM_024728.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 52/402 reads (13%) | catalogued as rs745753530, COSV59316072; called by mutect2, pindel, varscan2
- SULF1 | c.1689A>C p.E563D | Missense Mutation (SNP) | VAF 84/526 reads (16%) | SIFT tolerated (0.68); PolyPhen benign (0.028); catalogued as COSV52673317; called by muse, mutect2, varscan2
- SULF2 | c.128G>A p.R43H | Missense Mutation (SNP) | VAF 62/396 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1029474868; called by muse, varscan2
- SVEP1 | c.7535C>T p.T2512M | Missense Mutation (SNP) | VAF 77/444 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.727); catalogued as rs200375910; called by muse, mutect2, varscan2
- SYNE3 | c.896C>T p.T299I | Missense Mutation (SNP) | VAF 45/442 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.118); catalogued as rs780110039; called by muse, mutect2, varscan2
- SYNGAP1 | c.1786C>T p.R596C | Missense Mutation (SNP) | VAF 99/578 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767918800; called by muse, mutect2, varscan2
- SYT5 | c.1096C>T p.R366W | Missense Mutation (SNP) | VAF 109/502 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1275868735; called by muse, mutect2, varscan2
- TACC3 | c.47del p.N16Ifs*38 | Frame Shift Del (DEL) | VAF 64/379 reads (17%) | catalogued as rs757069381; called by mutect2, pindel, varscan2
- TADA3 | c.1003G>A p.A335T | Missense Mutation (SNP) | VAF 67/453 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0.18); catalogued as rs150292231, COSV57334284; called by muse, mutect2, varscan2
- TAMALIN | c.902del p.P301Rfs*28 | Frame Shift Del (DEL) | VAF 33/231 reads (14%) | catalogued as rs1475020529; called by mutect2, pindel, varscan2
- TANGO6 | c.1223G>A p.R408H | Missense Mutation (SNP) | VAF 34/410 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs758399130, COSV55768866; called by muse, mutect2
- TBC1D2 | c.2347G>A p.V783M | Missense Mutation (SNP) | VAF 56/389 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs371626516; called by muse, mutect2, varscan2
- TBC1D2 | c.1537G>A p.G513S | Missense Mutation (SNP) | VAF 68/436 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0.041); catalogued as rs574202141, COSV59784639; called by muse, mutect2, varscan2
- TBL3 | c.442C>T p.R148* | Nonsense Mutation (SNP) | VAF 70/416 reads (17%) | catalogued as rs1291848000, COSV60341053; called by muse, mutect2, varscan2
- TBL3 | c.910G>A p.A304T | Missense Mutation (SNP) | VAF 70/456 reads (15%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as rs766179118; called by muse, mutect2, varscan2
- TBX3 | c.1414G>A p.A472T (on ENST00000257566 / NM_016569.4; = p.A452T on NM_005996.4) | Missense Mutation (SNP) | VAF 113/658 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs1302202171, COSV99983912; called by muse, mutect2, varscan2
- TCEAL8 | c.65G>A p.R22H | Missense Mutation (SNP) | VAF 39/256 reads (15%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs1278456291, COSV100749822; called by muse, mutect2, varscan2
- TCHH | c.2590C>T p.R864* | Nonsense Mutation (SNP) | VAF 72/480 reads (15%) | catalogued as COSV64273288; called by muse, varscan2
- TEAD3 | c.1069C>T p.R357C | Missense Mutation (SNP) | VAF 71/355 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs935947869, COSV58816968; called by muse, mutect2, varscan2
- TENM3 | c.2438G>A p.R813Q | Missense Mutation (SNP) | VAF 81/374 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs373394131, COSV69316690; called by muse, mutect2, varscan2
- TENT2 | c.1435G>A p.A479T | Missense Mutation (SNP) | VAF 33/213 reads (15%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.36); catalogued as rs1172295499; called by muse, mutect2, varscan2
- TENT4B | c.151A>G p.S51G (on ENST00000561678 / NM_001365323.2; = p.S36G on NM_001040284.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/197 reads (15%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs934424686, COSV62547274; called by mutect2, varscan2
- TEP1 | c.2722C>T p.R908* | Nonsense Mutation (SNP) | VAF 64/306 reads (21%) | catalogued as rs753534576; called by muse, mutect2, varscan2
- TET1 | c.1790G>T p.C597F | Missense Mutation (SNP) | VAF 78/361 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV65385401; called by muse, varscan2
- TET1 | c.3814T>C p.S1272P | Missense Mutation (SNP) | VAF 60/320 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.367); catalogued as rs750644966; called by muse, mutect2, varscan2
- TFEC | c.422del p.K141Rfs*42 | Frame Shift Del (DEL) | VAF 38/180 reads (21%) | catalogued as rs771133493, COSV55406589; called by mutect2, varscan2
- TH | c.1450C>T p.R484C (on ENST00000381178 / NM_199292.3; = p.R453C on NM_000360.4) | Missense Mutation (SNP) | VAF 69/394 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755922032, COSV51747352; called by muse, mutect2, varscan2
- THSD7A | c.656G>A p.R219H | Missense Mutation (SNP) | VAF 77/419 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749795557, COSV101448547, COSV101448565; called by muse, mutect2, varscan2
- TIAM1 | c.3412C>T p.R1138C | Missense Mutation (SNP) | VAF 47/335 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54553579; called by muse, mutect2, varscan2
- TIMM13 | c.88A>G p.I30V | Missense Mutation (SNP) | VAF 58/341 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.268); catalogued as COSV99295922; called by muse, mutect2, varscan2
- TIPARP | c.1748T>A p.V583D | Missense Mutation (SNP) | VAF 56/339 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.269); catalogued as rs752819159; called by muse, mutect2, varscan2
- TJP3 | c.2603G>A p.G868E | Missense Mutation (SNP) | VAF 55/318 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1311117041; called by muse, mutect2, varscan2
- TM7SF2 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 89/583 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs1412529879; called by muse, mutect2, varscan2
- TMED3 | c.458C>T p.T153M | Missense Mutation (SNP) | VAF 67/308 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.108); catalogued as rs756104785, COSV55302892; called by muse, mutect2, varscan2
- TMEM129 | c.883G>A p.V295M | Missense Mutation (SNP) | VAF 77/435 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.862); catalogued as rs1325074373; called by muse, mutect2, varscan2
- TMEM147 | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 26/306 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748318840, COSV52866530; called by muse, mutect2
- TMEM177 | c.216A>G p.I72M | Missense Mutation (SNP) | VAF 24/503 reads (5%) | SIFT tolerated (0.9); PolyPhen benign (0.005); catalogued as rs1481773897; called by muse, mutect2
- TMEM213 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 71/335 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.061); catalogued as rs753176491; called by muse, mutect2, varscan2
- TMEM248 | c.352C>A p.L118I | Missense Mutation (SNP) | VAF 108/484 reads (22%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.731); catalogued as rs749391502; called by muse, mutect2, varscan2
- TMEM249 | c.352C>T p.R118C | Missense Mutation (SNP) | VAF 116/710 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.167); catalogued as rs1334755395; called by muse, mutect2, varscan2
- TMEM26 | c.811G>A p.V271M | Missense Mutation (SNP) | VAF 99/447 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.886); catalogued as COSV53262651, COSV53264427; called by muse, mutect2, varscan2
- TMPRSS12 | c.176C>T p.A59V | Missense Mutation (SNP) | VAF 36/440 reads (8%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.019); catalogued as rs530297215, COSV68256277; called by muse, mutect2
- TNPO3 | c.2153G>A p.R718Q | Missense Mutation (SNP) | VAF 48/288 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs370591499; called by muse, mutect2, varscan2
- TOP3A | c.2057G>A p.R686H | Missense Mutation (SNP) | VAF 50/291 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs376624260; called by muse, mutect2, varscan2
- TOP3B | c.1492G>A p.E498K | Missense Mutation (SNP) | VAF 46/329 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs779209877, COSV64116380; called by muse, mutect2, varscan2
- TOX2 | c.586G>A p.A196T (on ENST00000358131 / NM_001098798.2; = p.A145T on NM_032883.3) | Missense Mutation (SNP) | VAF 86/482 reads (18%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs761415679, COSV100364346; called by muse, mutect2, varscan2
- TPBGL | c.675del p.P227Rfs*45 | Frame Shift Del (DEL) | VAF 65/480 reads (14%) | catalogued as rs1403498769; called by mutect2, pindel, varscan2
- TRAK1 | c.1601G>T p.R534L (on ENST00000327628 / NM_001349247.2; = p.R476L on NM_014965.5) | Missense Mutation (SNP) | VAF 92/540 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs1382861013; called by muse, mutect2, varscan2
- TRAK2 | c.1972G>A p.A658T | Missense Mutation (SNP) | VAF 28/198 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs866836205; called by muse, mutect2, varscan2
- TRANK1 | c.2875G>A p.E959K | Missense Mutation (SNP) | VAF 72/372 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.097); catalogued as rs755000515, COSV57166317; called by muse, mutect2, varscan2
- TRAPPC12 | c.497G>A p.R166H | Missense Mutation (SNP) | VAF 118/643 reads (18%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.266); catalogued as rs780055160; called by muse, mutect2, varscan2
- TRAPPC9 | c.2909G>A p.R970Q | Missense Mutation (SNP) | VAF 52/531 reads (10%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.738); catalogued as rs780452862, CM145751; called by muse, mutect2
- TRIM2 | c.226G>A p.A76T (on ENST00000437508; = p.A103T on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 76/401 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs762582474; called by muse, mutect2, varscan2
- TRIM25 | c.1679C>T p.A560V | Missense Mutation (SNP) | VAF 92/436 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.136); catalogued as COSV57545339; called by muse, mutect2, varscan2
- TRIM3 | c.386C>T p.A129V | Missense Mutation (SNP) | VAF 47/349 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV61985591; called by muse, mutect2, varscan2
- TRIM49B | c.493A>G p.T165A | Missense Mutation (SNP) | VAF 21/179 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs1432983002, COSV60320735; called by muse, mutect2, varscan2
- TRIM56 | c.1682C>T p.A561V | Missense Mutation (SNP) | VAF 106/548 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs368846650; called by muse, mutect2, varscan2
- TRIM64 | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 50/266 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs1180139373; called by muse, mutect2, varscan2
- TRIML2 | c.602G>A p.G201D | Missense Mutation (SNP) | VAF 13/324 reads (4%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV100455974, COSV58719689; called by muse, mutect2
- TRIP4 | c.1213C>T p.R405C | Missense Mutation (SNP) | VAF 69/347 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.2); catalogued as rs145666096; called by muse, mutect2, varscan2
- TRPM8 | c.2683C>T p.R895C | Missense Mutation (SNP) | VAF 69/358 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1470605742, COSV61220763; called by muse, mutect2, varscan2
- TSHZ2 | c.2454del p.M819* | Frame Shift Del (DEL) | VAF 92/474 reads (19%) | catalogued as COSV100295175, COSV100295449; called by mutect2, varscan2
- TSSK2 | c.825del p.K276Sfs*30 | Frame Shift Del (DEL) | VAF 84/463 reads (18%) | catalogued as rs764514103; called by mutect2, pindel, varscan2
- TTBK1 | c.1735G>A p.E579K | Missense Mutation (SNP) | VAF 76/560 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as rs771856576; called by muse, mutect2, varscan2
- TTC38 | c.1334G>A p.R445H | Missense Mutation (SNP) | VAF 64/330 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372998054; called by muse, mutect2, varscan2
- TTLL11 | c.982G>A p.D328N | Missense Mutation (SNP) | VAF 29/219 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs373543178; called by muse, mutect2, varscan2
- TTLL4 | c.3074G>A p.R1025Q | Missense Mutation (SNP) | VAF 72/385 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1004632019, COSV51435172, COSV99292981; called by muse, mutect2, varscan2
- TTN | c.48357A>C p.E16119D (on ENST00000591111; = p.E8695D on NM_003319.4) | Missense Mutation (SNP) | VAF 98/258 reads (38%) | PolyPhen benign (0.074); catalogued as COSV59905709; called by muse, mutect2, varscan2
- UBR5 | c.6360del p.E2121Kfs*28 | Frame Shift Del (DEL) | VAF 66/442 reads (15%) | catalogued as rs763652408; called by mutect2, varscan2
- UHRF1BP1 | c.3996del p.I1333Sfs*20 | Frame Shift Del (DEL) | VAF 27/232 reads (12%) | catalogued as COSV51954201; called by mutect2, pindel, varscan2
- UNC79 | c.3839T>G p.L1280R (on ENST00000393151 / NM_001346218.2; = p.L1103R on NM_020818.5) | Missense Mutation (SNP) | VAF 75/439 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56373959; called by muse, mutect2, varscan2
- UNC79 | c.3968G>A p.G1323D (on ENST00000393151 / NM_001346218.2; = p.G1146D on NM_020818.5) | Missense Mutation (SNP) | VAF 85/442 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.646); catalogued as rs753210291; called by muse, mutect2, varscan2
- UNC80 | c.1724C>T p.A575V | Missense Mutation (SNP) | VAF 30/294 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.991); catalogued as COSV55889012; called by muse, mutect2, varscan2
- UNKL | c.2021G>A p.R674H (on ENST00000389221 / NM_001372107.1; = p.R170H on NM_001276414.2) | Missense Mutation (SNP) | VAF 55/329 reads (17%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.926); catalogued as rs771207208; called by muse, mutect2, varscan2
- URI1 | c.399del p.V134* | Frame Shift Del (DEL) | VAF 38/219 reads (17%) | catalogued as rs1568443871; called by mutect2, pindel, varscan2
- USH2A | c.11008G>A p.E3670K | Missense Mutation (SNP) | VAF 42/259 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.508); catalogued as rs140548353; ClinVar: likely benign; called by muse, mutect2, varscan2
- USP35 | c.113G>A p.C38Y | Missense Mutation (SNP) | VAF 80/484 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs781174258; called by muse, mutect2, varscan2
- UST | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 50/346 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.466); catalogued as COSV66545698; called by muse, varscan2
- UTP11 | c.74G>A p.R25Q | Missense Mutation (SNP) | VAF 48/232 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65951285; called by muse, mutect2, varscan2
- VCL | c.2827C>A p.P943T | Missense Mutation (SNP) | VAF 75/357 reads (21%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.013); catalogued as rs71579375; called by muse, mutect2, varscan2
- VPS13C | c.6769G>A p.A2257T (on ENST00000644861 / NM_020821.3; = p.A2214T on NM_017684.5) | Missense Mutation (SNP) | VAF 64/302 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.411); catalogued as COSV99828785; called by muse, mutect2, varscan2
- VSIG10L | c.317C>T p.P106L | Missense Mutation (SNP) | VAF 66/282 reads (23%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs924521090, COSV58537031; called by muse, varscan2
- VSTM1 | c.102G>A p.W34* | Nonsense Mutation (SNP) | VAF 33/564 reads (6%) | catalogued as rs1161212228; called by muse, mutect2
- WASF3 | c.27G>T p.E9D | Missense Mutation (SNP) | VAF 31/188 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.188); catalogued as COSV58965356; called by muse, mutect2, varscan2
- WASL | c.1263del p.V422Wfs*17 | Frame Shift Del (DEL) | VAF 86/464 reads (19%) | catalogued as rs1158703313; called by mutect2, pindel, varscan2
- WDR4 | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 61/388 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs146933186; called by muse, mutect2, varscan2
- WDTC1 | c.494G>A p.R165Q | Missense Mutation (SNP) | VAF 43/253 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757186775, COSV100088724; called by muse, mutect2, varscan2
- WDTC1 | c.868del p.E290Nfs*8 | Frame Shift Del (DEL) | VAF 36/212 reads (17%) | catalogued as rs747972901, COSV60089251; called by mutect2, varscan2
- WHRN | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 95/501 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as rs1388198744; called by muse, mutect2, varscan2
- WNT2B | c.676C>T p.R226C (on ENST00000369684 / NM_024494.3; = p.R207C on NM_004185.4) | Missense Mutation (SNP) | VAF 37/255 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs377518381; called by muse, mutect2, varscan2
- WNT4 | c.1051C>T p.R351* | Nonsense Mutation (SNP) | VAF 48/246 reads (20%) | catalogued as rs780694720, COSV51604031; called by muse, mutect2, varscan2
- WNT5B | c.905G>A p.R302H | Missense Mutation (SNP) | VAF 71/418 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60198259; called by muse, mutect2, varscan2
- WNT7B | c.476G>A p.G159D | Missense Mutation (SNP) | VAF 74/463 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59750703; called by muse, mutect2, varscan2
- XIRP2 | c.313C>T p.R105C | Missense Mutation (SNP) | VAF 75/445 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.112); catalogued as rs780403837, COSV54695932, COSV99746418; called by muse, mutect2, varscan2
- YBX1 | c.835C>T p.R279C | Missense Mutation (SNP) | VAF 64/400 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as rs371459628; called by muse, varscan2
- YEATS2 | c.859G>A p.V287I | Missense Mutation (SNP) | VAF 45/302 reads (15%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.627); catalogued as rs200810151; called by muse, varscan2
- YRDC | c.703C>T p.R235C | Missense Mutation (SNP) | VAF 59/352 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.643); catalogued as rs938979599, COSV61116777; called by muse, mutect2, varscan2
- ZAR1 | c.57dup p.C20Lfs*332 | Frame Shift Ins (INS) | VAF 92/503 reads (18%) | catalogued as rs757396573; called by mutect2, varscan2
- ZC3H18 | c.2037dup p.R680Qfs*14 | Frame Shift Ins (INS) | VAF 54/378 reads (14%) | catalogued as rs751577786; called by mutect2, varscan2
- ZC3H3 | c.1897C>T p.R633C | Missense Mutation (SNP) | VAF 48/312 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs769828841, COSV52791418; called by muse, mutect2, varscan2
- ZCCHC4 | c.960del p.F320Lfs*19 | Frame Shift Del (DEL) | VAF 44/298 reads (15%) | catalogued as rs760215323; called by mutect2, pindel, varscan2
- ZDHHC13 | c.1351C>T p.R451* | Nonsense Mutation (SNP) | VAF 45/284 reads (16%) | catalogued as rs746087347, COSV67980952; called by muse, mutect2, varscan2
- ZDHHC8 | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 37/329 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as COSV100272466; called by muse, mutect2
- ZFAT | c.1421G>A p.R474H | Missense Mutation (SNP) | VAF 92/534 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs374372896, COSV64735305; called by muse, varscan2
- ZFHX4 | c.2377C>T p.H793Y | Missense Mutation (SNP) | VAF 66/400 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99070785; called by muse, mutect2, varscan2
- ZFHX4 | c.8284C>G p.L2762V | Missense Mutation (SNP) | VAF 60/426 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.237); catalogued as rs1338040271; called by muse, mutect2, varscan2
- ZFP62 | c.1657C>T p.R553* (on ENST00000502412 / NM_001377944.1; = p.R520* on NM_152283.5 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 85/429 reads (20%) | catalogued as rs897936540, COSV100772736; called by muse, mutect2, varscan2
- ZFP62 | c.503G>A p.R168H (on ENST00000502412 / NM_001377944.1; = p.R135H on NM_152283.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/484 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.227); catalogued as rs141026256; called by muse, mutect2
- ZMYM2 | c.434A>G p.E145G | Missense Mutation (SNP) | VAF 50/388 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as rs909058735; called by muse, mutect2, varscan2
- ZNF205 | c.185C>T p.S62L | Missense Mutation (SNP) | VAF 88/449 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs758186740, COSV54621823; called by muse, mutect2, varscan2
- ZNF236 | c.1270G>A p.A424T | Missense Mutation (SNP) | VAF 66/374 reads (18%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs942309397; called by muse, varscan2
- ZNF343 | c.620G>A p.G207D | Missense Mutation (SNP) | VAF 40/482 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.018); catalogued as rs1406350524; called by muse, mutect2
1,156 further variants in this file (669 protein-altering or splice-affecting, 411 silent, 76 other) are not listed here.
